Somatic mutation profile of tumor specimen TCGA-AD-6889-01A (aliquot TCGA-AD-6889-01A-11D-1924-10) from TCGA case TCGA-AD-6889, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Ascending colon; AJCC pathologic stage: Stage IIA.
Specimen TCGA-AD-6889-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 154189c0-5f30-4e69-920c-c29e16ace6cb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AD-6889-10A (Blood Derived Normal), aliquot TCGA-AD-6889-10A-01D-1924-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4304ebce-c56d-40de-b369-143c761a2ab3

The open-access MAF lists 2,082 somatic variants for this specimen: 1,575 protein-altering or splice-affecting, 460 silent, 47 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 1,036, Silent 460, Frame Shift Del 317, Frame Shift Ins 93, Nonsense Mutation 70, Splice Site 30, Intron 25, In Frame Del 16, Splice Region 13, 3'UTR 7, RNA 6, 3'Flank 4.

Variants (750 of 2,082; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTS13 | c.304C>T p.R102C | Missense Mutation (SNP) | VAF 22/45 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs121908469, CM012887, COSV63020562; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AKT1 | c.49G>A p.E17K | Missense Mutation (SNP) | VAF 15/30 reads (50%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121434592, COSV62571334, COSV62576849; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- BARD1 | c.623del p.K208Rfs*4 | Frame Shift Del (DEL) | VAF 36/186 reads (19%) | catalogued as rs587780033; ClinVar: pathogenic; called by mutect2, varscan2
- BCHE | c.1027dup p.T343Nfs*8 | Frame Shift Ins (INS) | VAF 83/190 reads (44%) | catalogued as rs754214624; ClinVar: likely pathogenic; called by mutect2, varscan2
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- CACNA1F | c.2683C>T p.R895* | Nonsense Mutation (SNP) | VAF 23/25 reads (92%) | catalogued as rs122456135, CM980291, COSV59903610; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CSPP1 | c.2831del p.N944Mfs*2 (on ENST00000676605; = p.N903Mfs*2 on NM_024790.6) | Frame Shift Del (DEL) | VAF 16/44 reads (36%) | catalogued as rs863225190, COSV51582895; ClinVar: pathogenic; called by mutect2, varscan2
- DGKE | c.610del p.T204Qfs*6 | Frame Shift Del (DEL) | VAF 94/268 reads (35%) | catalogued as rs147972030; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- FGD1 | c.527del p.P176Hfs*39 | Frame Shift Del (DEL) | VAF 12/14 reads (86%) | catalogued as rs756586058; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- FLNB | c.1592del p.G531Dfs*42 | Frame Shift Del (DEL) | VAF 16/43 reads (37%) | catalogued as rs746105983; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- HPSE2 | c.57dup p.A20Rfs*45 | Frame Shift Ins (INS) | VAF 24/66 reads (36%) | catalogued as rs778121647; ClinVar: pathogenic; called by mutect2, varscan2
- LDLR | c.1221C>T p.H407= | Silent (SNP) | VAF 44/91 reads (48%) | catalogued as rs778424518, COSV52942267; ClinVar: likely pathogenic / likely benign; called by muse, mutect2, varscan2
- MFRP | c.3del p.H2Tfs*100 (on ENST00000449574; = p.H384Tfs*94 on NM_031433.4) | Frame Shift Del (DEL) | VAF 10/23 reads (43%) | catalogued as rs587776595; ClinVar: pathogenic; called by pindel, varscan2
- MLH1 | c.588dup p.Q197Tfs*7 | Frame Shift Ins (INS) | VAF 59/151 reads (39%) | catalogued as rs63751653; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- NPHS1 | c.3554dup p.S1186Vfs*10 | Frame Shift Ins (INS) | VAF 16/41 reads (39%) | catalogued as rs750714387; ClinVar: likely pathogenic; called by mutect2, pindel, varscan2
- SZT2 | c.5165G>A p.R1722H (on ENST00000634258 / NM_001365999.1; = p.R1665H on NM_015284.4) | Missense Mutation (SNP) | VAF 29/69 reads (42%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.629); catalogued as rs562214305, COSV65168290; ClinVar: uncertain significance / pathogenic; called by muse, mutect2, varscan2
- TCF20 | c.364dup p.Q122Pfs*12 | Frame Shift Ins (INS) | VAF 23/52 reads (44%) | catalogued as rs777979354; ClinVar: pathogenic; called by mutect2, varscan2
- A2M | c.686T>C p.F229S | Missense Mutation (SNP) | VAF 83/244 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs763515018, COSV59384251, COSV59390242; called by muse, mutect2, varscan2
- A2ML1 | c.2769G>T p.K923N | Missense Mutation (SNP) | VAF 28/66 reads (42%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as COSV55287681; called by muse, mutect2, varscan2
- AADACL3 | c.277C>T p.R93C | Missense Mutation (SNP) | VAF 28/75 reads (37%) | SIFT tolerated (0.29); PolyPhen benign (0.007); catalogued as rs376097711; called by muse, mutect2
- AANAT | c.394C>T p.Q132* | Nonsense Mutation (SNP) | VAF 14/24 reads (58%) | catalogued as COSV51683852; called by muse, mutect2, varscan2
- ABCA10 | c.1763A>G p.E588G | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52219873; called by muse, mutect2, varscan2
- ABCA3 | c.1018C>T p.R340C | Missense Mutation (SNP) | VAF 27/59 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.141); catalogued as rs760874963, COSV57051077; called by muse, mutect2, varscan2
- ABCB4 | c.1570A>G p.T524A | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as COSV55933439; called by muse, mutect2, varscan2
- ABCC1 | c.1651T>G p.F551V | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as COSV60682518; called by muse, mutect2
- ABCF3 | c.2018T>C p.V673A | Missense Mutation (SNP) | VAF 75/193 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.222); catalogued as rs991308869, COSV53051759; called by muse, mutect2, varscan2
- ABHD16A | c.431G>T p.R144M | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.275); catalogued as COSV101013331, COSV65451512; called by muse, mutect2, varscan2
- ABHD2 | c.551A>G p.E184G | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV61773252; called by muse, mutect2, varscan2
- ABL1 | c.166G>A p.A56T | Missense Mutation (SNP) | VAF 45/100 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.009); catalogued as rs369393102; called by muse, mutect2, varscan2
- AC013489.1 | c.952C>T p.R318C | Missense Mutation (SNP) | VAF 35/95 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); catalogued as rs762523583, COSV51550593; called by muse, mutect2, varscan2
- AC134980.2 | c.373G>A p.A125T | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.253); catalogued as rs767898516, COSV60908376; called by mutect2, varscan2
- AC231657.3 | c.625C>T p.R209C | Missense Mutation (SNP) | VAF 7/8 reads (88%) | SIFT deleterious (0); PolyPhen possibly damaging (0.569); catalogued as COSV59875624; called by muse, mutect2, varscan2
- ACAT2 | c.874A>G p.I292V | Missense Mutation (SNP) | VAF 49/118 reads (42%) | SIFT tolerated (0.33); PolyPhen benign (0.007); catalogued as rs774247391, COSV58457880; called by muse, mutect2, varscan2
- ACOX1 | c.20G>T p.R7M | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.04); catalogued as COSV53131951; called by muse, mutect2, varscan2
- ACP7 | c.217C>T p.R73C | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0.394); catalogued as rs370680976, COSV100488589; called by muse, mutect2, varscan2
- ACSM6 | c.715T>C p.S239P | Missense Mutation (SNP) | VAF 45/112 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV58977836; called by muse, mutect2, varscan2
- ACTG1 | c.1010A>G p.Y337C | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV59509952; called by muse, mutect2, varscan2
- ACTL7B | c.1168C>A p.L390M | Missense Mutation (SNP) | VAF 33/71 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65927033; called by muse, mutect2, varscan2
- ACVRL1 | c.523G>T p.G175W | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.208); catalogued as COSV66359798, COSV66361136; called by muse, mutect2, varscan2
- ADAL | c.651dup p.E218Rfs*11 | Frame Shift Ins (INS) | VAF 21/72 reads (29%) | catalogued as rs778831705; called by mutect2, varscan2
- ADAM15 | c.747C>T p.F249= | Splice Region (SNP) | VAF 9/20 reads (45%) | catalogued as COSV55125821, COSV55126633; called by muse, mutect2, varscan2
- ADAMTS17 | c.1721del p.P575Lfs*13 | Frame Shift Del (DEL) | VAF 8/30 reads (27%) | catalogued as rs779966272; called by mutect2, pindel
- ADAMTS2 | c.3223del p.V1075Sfs*32 | Frame Shift Del (DEL) | VAF 28/82 reads (34%) | catalogued as COSV52368418, COSV52368929; called by mutect2, pindel, varscan2
- ADAMTS5 | c.422G>A p.R141H | Missense Mutation (SNP) | VAF 30/66 reads (45%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.781); catalogued as rs751039845, COSV53177092, COSV53177777; called by muse, mutect2, varscan2
- ADCY5 | c.908A>G p.Y303C | Missense Mutation (SNP) | VAF 16/26 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs757908717, COSV71901316; called by muse, mutect2, varscan2
- ADCY6 | c.745G>A p.A249T | Missense Mutation (SNP) | VAF 44/117 reads (38%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs760708097, COSV57166785; called by muse, mutect2, varscan2
- ADGRV1 | c.626del p.P209Lfs*6 | Frame Shift Del (DEL) | VAF 74/188 reads (39%) | catalogued as rs756977835, COSV101316537, COSV67977494; called by mutect2, pindel, varscan2
- ADGRV1 | c.9745A>G p.M3249V | Missense Mutation (SNP) | VAF 35/81 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.006); catalogued as COSV67981028; called by muse, mutect2, varscan2
- ADRA2A | c.1372C>T p.R458W | Missense Mutation (SNP) | VAF 35/78 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV99701773; called by muse, mutect2, varscan2
- ADRB3 | c.716G>A p.R239H | Missense Mutation (SNP) | VAF 37/80 reads (46%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.953); catalogued as rs772787340, COSV100799982; called by muse, mutect2
- ADSS1 | c.1232C>T p.A411V | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV58272652; called by muse, mutect2, varscan2
- AFAP1L2 | c.2068C>T p.R690W | Missense Mutation (SNP) | VAF 50/144 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs767778015, COSV58412347; called by muse, mutect2, varscan2
- AGRN | c.3685G>T p.V1229L | Missense Mutation (SNP) | VAF 30/87 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.042); catalogued as COSV65068431; called by muse, mutect2, varscan2
- AHCTF1 | c.2258G>T p.W753L (on ENST00000366508; = p.W727L on NM_015446.5) | Missense Mutation (SNP) | VAF 62/128 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV100404280; called by muse, mutect2, varscan2
- AHI1 | c.352G>T p.E118* | Nonsense Mutation (SNP) | VAF 175/433 reads (40%) | catalogued as COSV55624714; called by muse, mutect2, varscan2
- AHNAK | c.9911G>A p.G3304D | Missense Mutation (SNP) | VAF 49/102 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs370886395; called by muse, mutect2, varscan2
- AHNAK2 | c.6560T>C p.M2187T | Missense Mutation (SNP) | VAF 56/140 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.127); catalogued as COSV60911018; called by muse, mutect2, varscan2
- AHRR | c.1113-2A>G p.X371_splice | Splice Site (SNP) | VAF 34/64 reads (53%) | catalogued as COSV57084095; called by muse, mutect2, varscan2
- AKT1S1 | c.599C>T p.A200V (on ENST00000344175 / NM_001098633.4; = p.A220V on NM_032375.5) | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT tolerated (0.15); PolyPhen benign (0.086); catalogued as rs142575650; called by muse, mutect2, varscan2
- ALDH1A1 | c.1337C>A p.A446D | Missense Mutation (SNP) | VAF 78/183 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.834); catalogued as rs1803054, COSV52789868; called by muse, mutect2, varscan2
- ALDH8A1 | c.724C>A p.L242M | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0.026); catalogued as COSV55640806; called by muse, mutect2, varscan2
- ALPI | c.913C>A p.P305T | Missense Mutation (SNP) | VAF 88/169 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55013979; called by muse, mutect2, varscan2
- ALS2CL | c.1859A>C p.E620A | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV59670747; called by muse, mutect2, varscan2
- ANK2 | c.3373G>T p.D1125Y | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52152098; called by muse, mutect2, varscan2
- ANKIB1 | c.437del p.N146Tfs*12 | Frame Shift Del (DEL) | VAF 9/19 reads (47%) | catalogued as rs201434379; called by mutect2, varscan2
- ANKIB1 | c.580G>T p.A194S | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99729788; called by muse, varscan2
- ANKIB1 | c.613C>T p.R205W | Missense Mutation (SNP) | VAF 46/85 reads (54%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.862); catalogued as rs191723687; called by muse, varscan2
- ANKLE2 | c.1607G>A p.R536H | Missense Mutation (SNP) | VAF 25/51 reads (49%) | SIFT tolerated (0.18); PolyPhen benign (0.067); catalogued as rs751246267, COSV61708389; called by muse, mutect2, varscan2
- ANKRD13C | c.1304A>G p.H435R | Missense Mutation (SNP) | VAF 57/145 reads (39%) | SIFT tolerated (0.61); PolyPhen benign (0.066); catalogued as COSV52029837; called by muse, mutect2, varscan2
- ANKRD26 | c.1340dup p.N447Kfs*5 | Frame Shift Ins (INS) | VAF 16/63 reads (25%) | catalogued as rs779946717; called by mutect2, varscan2
- ANKRD44 | c.713A>G p.Y238C | Missense Mutation (SNP) | VAF 38/110 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.199); catalogued as rs1338962767, COSV56551294; called by muse, mutect2, varscan2
- ANKRD53 | c.329A>G p.Y110C | Missense Mutation (SNP) | VAF 39/83 reads (47%) | SIFT tolerated (0.13); PolyPhen benign (0.049); catalogued as COSV99721519; called by muse, mutect2, varscan2
- ANO9 | c.952T>C p.Y318H | Missense Mutation (SNP) | VAF 60/73 reads (82%) | SIFT tolerated (0.56); PolyPhen benign (0.209); catalogued as COSV60448788; called by muse, mutect2, varscan2
- ANXA13 | c.451dup p.I151Nfs*9 | Frame Shift Ins (INS) | VAF 63/140 reads (45%) | catalogued as rs759218332; called by mutect2, varscan2
- ANXA6 | c.1207C>T p.Q403* | Nonsense Mutation (SNP) | VAF 38/88 reads (43%) | catalogued as COSV62905885; called by muse, mutect2, varscan2
- AOX1 | c.1909G>A p.G637S | Missense Mutation (SNP) | VAF 69/138 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs760074982, COSV65980752, COSV65983407; called by muse, mutect2, varscan2
- AP002748.5 | c.1174G>A p.V392I | Missense Mutation (SNP) | VAF 13/23 reads (57%) | SIFT tolerated (0.29); PolyPhen benign (0.082); catalogued as COSV100567870, COSV59147711; called by muse, mutect2, varscan2
- AP2A2 | c.2009C>T p.A670V | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV59958888; called by muse, mutect2, varscan2
- AP3D1 | c.3095C>A p.T1032N | Missense Mutation (SNP) | VAF 37/83 reads (45%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.562); catalogued as COSV61425915; called by muse, mutect2, varscan2
- AP5S1 | c.32G>T p.R11M | Missense Mutation (SNP) | VAF 29/48 reads (60%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.518); catalogued as rs1397170477, COSV55693765; called by muse, mutect2, varscan2
- AP5Z1 | c.2086del p.Q696Rfs*6 | Frame Shift Del (DEL) | VAF 14/36 reads (39%) | catalogued as rs771683676, COSV100804281; called by mutect2, pindel, varscan2
- AREL1 | c.913A>G p.T305A | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT tolerated (0.85); PolyPhen benign (0); catalogued as rs1476454669, COSV62665810; called by muse, mutect2, varscan2
- ARHGAP11A | c.1217C>T p.A406V | Missense Mutation (SNP) | VAF 21/132 reads (16%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.959); catalogued as COSV64380716; called by muse, mutect2, varscan2
- ARHGAP28 | c.1031G>A p.R344H (on ENST00000383472 / NM_001366230.1; = p.R185H on NM_001010000.3) | Missense Mutation (SNP) | VAF 53/125 reads (42%) | SIFT tolerated (0.56); PolyPhen possibly damaging (0.899); catalogued as rs764582880, COSV51634068; called by muse, mutect2, varscan2
- ARHGAP31 | c.96G>T p.Q32H | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.141); catalogued as COSV51790406; called by muse, mutect2, varscan2
- ARHGAP31 | c.892T>C p.S298P | Missense Mutation (SNP) | VAF 58/116 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.286); catalogued as COSV51790417; called by muse, mutect2, varscan2
- ARHGAP32 | c.1155G>A p.V385= (on ENST00000310343 / NM_001378025.1; = p.V36= on NM_014715.4) | Splice Region (SNP) | VAF 17/34 reads (50%) | catalogued as COSV59850057; called by muse, mutect2, varscan2
- ARHGAP35 | c.2371G>T p.G791* | Nonsense Mutation (SNP) | VAF 88/197 reads (45%) | catalogued as COSV68329875; called by muse, mutect2, varscan2
- ARHGAP35 | c.3455T>C p.V1152A | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as COSV68329881; called by muse, mutect2, varscan2
- ARHGAP9 | c.493C>A p.L165I | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT tolerated (0.25); PolyPhen benign (0.005); catalogued as COSV62721866; called by muse, mutect2, varscan2
- ARHGEF10L | c.159del p.S54Afs*12 | Frame Shift Del (DEL) | VAF 9/45 reads (20%) | catalogued as rs761682761, COSV63426739; called by mutect2, pindel, varscan2
- ARHGEF10L | c.895C>A p.P299T | Missense Mutation (SNP) | VAF 44/103 reads (43%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.72); catalogued as COSV51429732; called by muse, mutect2, varscan2
- ARHGEF26 | c.98G>A p.S33N | Missense Mutation (SNP) | VAF 33/76 reads (43%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as COSV62844892; called by muse, mutect2, varscan2
- ARHGEF28 | c.799C>G p.L267V | Missense Mutation (SNP) | VAF 79/172 reads (46%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.939); catalogued as COSV55250888; called by muse, mutect2, varscan2
- ARL4D | c.262C>T p.R88C | Missense Mutation (SNP) | VAF 32/79 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV60721351; called by muse, mutect2, varscan2
- ART5 | c.661G>A p.E221K | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs202122052, COSV63364250; called by muse, mutect2, varscan2
- ASB18 | c.1039C>T p.R347C | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.796); catalogued as COSV58234368; called by muse, mutect2
- ASCC2 | c.332A>G p.E111G | Missense Mutation (SNP) | VAF 45/92 reads (49%) | SIFT tolerated (0.12); PolyPhen benign (0.114); catalogued as COSV57072668; called by muse, mutect2, varscan2
- ASIC5 | c.1376C>T p.T459M | Missense Mutation (SNP) | VAF 67/155 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs752923424, COSV101611166; called by muse, mutect2, varscan2
- ASPM | c.3979C>T p.R1327* | Nonsense Mutation (SNP) | VAF 139/337 reads (41%) | catalogued as rs886039310, CM133216, COSV54126855; called by muse, mutect2, varscan2
- ATF6 | c.1981G>A p.V661I | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.066); catalogued as rs566071406, COSV63406555; called by muse, mutect2, varscan2
- ATF7IP2 | c.485G>A p.C162Y | Missense Mutation (SNP) | VAF 51/135 reads (38%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV61092598; called by muse, mutect2, varscan2
- ATP10B | c.1304C>T p.T435M | Missense Mutation (SNP) | VAF 51/118 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs775822343, COSV100469473, COSV58778150; called by muse, mutect2, varscan2
- ATP13A3 | c.2573G>A p.R858H | Missense Mutation (SNP) | VAF 14/201 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1271095571, COSV55462582; called by muse, mutect2
- ATP2B4 | c.367C>T p.R123C | Missense Mutation (SNP) | VAF 39/98 reads (40%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.814); catalogued as rs779601653, COSV58175453; called by muse, mutect2, varscan2
- ATP2B4 | c.2155T>C p.F719L | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT tolerated (0.1); PolyPhen benign (0.246); catalogued as COSV58175470; called by muse, mutect2, varscan2
- ATP2C2 | c.16G>A p.V6I | Missense Mutation (SNP) | VAF 21/45 reads (47%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.011); catalogued as COSV52293959; called by muse, mutect2, varscan2
- ATP2C2 | c.1831G>T p.G611* | Nonsense Mutation (SNP) | VAF 35/69 reads (51%) | catalogued as COSV52293969; called by muse, mutect2, varscan2
- ATP5F1C | c.809A>G p.K270R | Missense Mutation (SNP) | VAF 41/100 reads (41%) | SIFT tolerated (0.12); PolyPhen benign (0.076); catalogued as COSV59621189; called by muse, mutect2, varscan2
- ATXN2 | c.3308C>T p.A1103V (on ENST00000550104; = p.A943V on NM_002973.4) | Missense Mutation (SNP) | VAF 44/101 reads (44%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.119); catalogued as rs1287322286, COSV66483349, COSV66485298; called by muse, mutect2, varscan2
- AXIN1 | c.1295del p.P432Qfs*48 | Frame Shift Del (DEL) | VAF 10/26 reads (38%) | catalogued as rs1458136153; called by mutect2, pindel, varscan2
- B3GNT4 | c.253G>A p.A85T | Missense Mutation (SNP) | VAF 33/105 reads (31%) | SIFT tolerated (0.79); PolyPhen benign (0.005); catalogued as rs749136382, COSV57335968; called by muse, mutect2, varscan2
- B9D2 | c.308C>T p.P103L | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs761918700, COSV54683794, COSV99699133; called by muse, mutect2, varscan2
- BACH2 | c.632A>G p.D211G | Missense Mutation (SNP) | VAF 40/107 reads (37%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.647); catalogued as COSV100000655; called by muse, mutect2, varscan2
- BAG2 | c.257G>A p.R86H | Missense Mutation (SNP) | VAF 41/95 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs765872537, COSV58097547; called by muse, mutect2, varscan2
- BBX | c.2675C>T p.A892V (on ENST00000325805 / NM_001142568.3; = p.A862V on NM_020235.7) | Missense Mutation (SNP) | VAF 31/66 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.711); catalogued as COSV57881199; called by muse, mutect2, varscan2
- BCAM | c.1358C>T p.A453V | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.012); catalogued as rs766822712, COSV54301216; called by muse, mutect2, varscan2
- BCORL1 | c.3153G>T p.M1051I | Missense Mutation (SNP) | VAF 54/64 reads (84%) | SIFT tolerated (0.24); PolyPhen benign (0.138); catalogued as COSV54392284; called by muse, mutect2, varscan2
- BDP1 | c.2014G>C p.E672Q | Missense Mutation (SNP) | VAF 93/235 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.273); catalogued as COSV100703433; called by muse, varscan2
- BEND3 | c.890G>A p.R297H | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.873); catalogued as rs782329696, COSV64680382; called by muse, mutect2, varscan2
- BMP10 | c.1252G>A p.V418I | Missense Mutation (SNP) | VAF 36/95 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs767015446, COSV54894476; called by muse, mutect2, varscan2
- BMP3 | c.206C>T p.T69M | Missense Mutation (SNP) | VAF 26/62 reads (42%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs963222043, COSV51082128; called by muse, mutect2, varscan2
- BMPR2 | c.1748del p.N583Tfs*44 | Frame Shift Del (DEL) | VAF 42/95 reads (44%) | catalogued as rs772920507, COSV65808737; called by mutect2, pindel, varscan2
- BMS1 | c.622A>G p.T208A | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.565); catalogued as COSV65733222; called by muse, mutect2, varscan2
- BOC | c.3112G>A p.D1038N | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.011); catalogued as rs184384636; called by muse, mutect2, varscan2
- BPIFB6 | c.49C>T p.R17* | Nonsense Mutation (SNP) | VAF 37/73 reads (51%) | catalogued as rs761397117, COSV62754667; called by muse, mutect2, varscan2
- BRD3 | c.71del p.P24Rfs*24 | Frame Shift Del (DEL) | VAF 16/39 reads (41%) | catalogued as rs763134487; called by mutect2, varscan2
- BRD9 | c.883G>A p.A295T | Missense Mutation (SNP) | VAF 17/32 reads (53%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.766); catalogued as rs1307014886, COSV60245437; called by muse, mutect2, varscan2
- BRF1 | c.1358A>T p.D453V | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59266987; called by muse, mutect2, varscan2
- BRINP3 | c.1309G>A p.A437T | Missense Mutation (SNP) | VAF 41/93 reads (44%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV100818893, COSV66517294; called by muse, mutect2, varscan2
- BRSK1 | c.1135del p.R379Gfs*9 | Frame Shift Del (DEL) | VAF 7/21 reads (33%) | catalogued as rs746043904, COSV58665984; called by mutect2, varscan2
- BTBD10 | c.4G>A p.A2T | Missense Mutation (SNP) | VAF 28/56 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); catalogued as rs1336860905, COSV53398302; called by muse, mutect2, varscan2
- BTBD6 | c.1312G>A p.G438S | Missense Mutation (SNP) | VAF 20/33 reads (61%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs747308975, COSV59267000; called by muse, mutect2, varscan2
- BTNL9 | c.1315G>A p.A439T | Missense Mutation (SNP) | VAF 19/35 reads (54%) | SIFT tolerated (0.24); PolyPhen benign (0.104); catalogued as COSV59794659, COSV59799644; called by muse, mutect2, varscan2
- BUD23 | c.259A>G p.M87V | Missense Mutation (SNP) | VAF 64/147 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.803); catalogued as COSV56094470; called by muse, varscan2
- C11orf1 | c.167G>A p.R56Q | Missense Mutation (SNP) | VAF 28/68 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs782291488, COSV99500255; called by muse, mutect2, varscan2
- C6orf118 | c.706T>C p.F236L | Missense Mutation (SNP) | VAF 26/54 reads (48%) | SIFT tolerated (0.12); PolyPhen benign (0.062); catalogued as COSV57813588; called by muse, mutect2, varscan2
- C8A | c.370G>A p.G124S | Missense Mutation (SNP) | VAF 33/85 reads (39%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.723); catalogued as COSV100776707, COSV63483419; called by muse, mutect2, varscan2
- C8B | c.1273G>A p.V425I | Missense Mutation (SNP) | VAF 33/69 reads (48%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.833); catalogued as rs769416892, COSV64776877; called by muse, mutect2, varscan2
- C8G | c.299G>A p.R100H | Missense Mutation (SNP) | VAF 35/65 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.747); catalogued as rs374701186, COSV56403417; called by muse, mutect2, varscan2
- CAB39L | c.446G>A p.C149Y | Missense Mutation (SNP) | VAF 29/82 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100759623; called by muse, mutect2, varscan2
- CACNA1H | c.625G>A p.A209T | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs570207081, COSV61997273; called by mutect2, varscan2
- CALML4 | c.229A>G p.M77V | Missense Mutation (SNP) | VAF 42/92 reads (46%) | SIFT tolerated (0.22); PolyPhen benign (0.013); catalogued as rs779125634, COSV61205858; called by muse, varscan2
- CAMK2G | c.284G>A p.G95D | Missense Mutation (SNP) | VAF 38/70 reads (54%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV59480699; called by muse, mutect2, varscan2
- CAMTA1 | c.565G>T p.G189C | Missense Mutation (SNP) | VAF 31/56 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs146417182, COSV57888126; called by muse, mutect2, varscan2
- CAPRIN1 | c.966+2T>C p.X322_splice | Splice Site (SNP) | VAF 84/184 reads (46%) | catalogued as COSV100404176; called by muse, mutect2, varscan2
- CARD11 | c.2706C>T p.F902= | Splice Region (SNP) | VAF 19/46 reads (41%) | catalogued as rs372346149; called by muse, mutect2, varscan2
- CARD11 | c.1663del p.R555Gfs*45 | Frame Shift Del (DEL) | VAF 7/20 reads (35%) | catalogued as rs762770988, COSV62756627; called by mutect2, pindel, varscan2
- CASP5 | c.533del p.N178Ifs*8 | Frame Shift Del (DEL) | VAF 8/49 reads (16%) | catalogued as rs765105588; called by mutect2, varscan2
- CBFA2T2 | c.1313_1314insA p.W438* | Nonsense Mutation (INS) | VAF 9/38 reads (24%) | catalogued as COSV60797750; called by mutect2*, varscan2
- CBL | c.94G>A p.A32T | Missense Mutation (SNP) | VAF 12/20 reads (60%) | SIFT deleterious (0.05); PolyPhen benign (0.007); catalogued as COSV99876880; called by muse, varscan2
- CBLL2 | c.830C>T p.P277L | Missense Mutation (SNP) | VAF 108/118 reads (92%) | SIFT tolerated (0.06); PolyPhen benign (0.031); catalogued as COSV60368656; called by muse, mutect2, varscan2
- CBLN2 | c.614G>A p.G205D | Missense Mutation (SNP) | VAF 33/86 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV54050682; called by muse, mutect2, varscan2
- CCDC62 | c.1808C>T p.T603M | Missense Mutation (SNP) | VAF 28/69 reads (41%) | SIFT tolerated (0.05); PolyPhen benign (0.172); catalogued as rs761755699, COSV53431631; called by muse, mutect2, varscan2
- CCDC90B | c.593dup p.D199Gfs*13 | Frame Shift Ins (INS) | VAF 48/134 reads (36%) | catalogued as rs753456737; called by mutect2, pindel, varscan2
- CCDC92 | c.912G>T p.Q304H | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.003); catalogued as rs757094564, COSV53019043; called by muse, mutect2, varscan2
- CCDC9B | c.736G>A p.D246N | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs375488563, COSV66875059; called by muse, mutect2, varscan2
- CCDC9B | c.294del p.M99Wfs*3 | Frame Shift Del (DEL) | VAF 14/34 reads (41%) | catalogued as rs765438623; called by mutect2, pindel, varscan2
- CCER1 | c.410C>T p.P137L | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT deleterious (0.02); PolyPhen benign (0.294); catalogued as COSV62646324; called by muse, mutect2, varscan2
- CCNJL | c.1123G>T p.G375C | Missense Mutation (SNP) | VAF 29/51 reads (57%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.579); catalogued as COSV57443444; called by muse, mutect2, varscan2
- CCNJL | c.538C>A p.L180M | Missense Mutation (SNP) | VAF 70/155 reads (45%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.786); catalogued as COSV57443454; called by muse, mutect2, varscan2
- CCR10 | c.214G>A p.A72T | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV52848767; called by muse, mutect2, varscan2
- CCR3 | c.196C>T p.R66* | Nonsense Mutation (SNP) | VAF 18/158 reads (11%) | catalogued as rs201795127, COSV100656718; called by muse, mutect2, varscan2
- CD163L1 | c.3484G>A p.G1162R | Missense Mutation (SNP) | VAF 43/112 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs779749979, COSV58012340; called by muse, mutect2, varscan2
- CD6 | c.988T>C p.C330R | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV57836631; called by muse, mutect2, varscan2
- CDC42BPA | c.4627C>T p.R1543C (on ENST00000334218 / NM_001366019.2; = p.R1530C on NM_003607.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 36/260 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs779106707, COSV62005872; called by muse, mutect2, varscan2
- CDCA7L | c.824C>T p.A275V | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs778002499, COSV60938162; called by muse, mutect2, varscan2
- CDH13 | c.443C>A p.P148Q | Missense Mutation (SNP) | VAF 53/123 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV51802171; called by muse, mutect2, varscan2
- CDH23 | c.9059G>A p.R3020H | Missense Mutation (SNP) | VAF 31/71 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.011); catalogued as rs767052814, COSV56450759; called by muse, mutect2, varscan2
- CDK16 | c.1154C>T p.T385M | Missense Mutation (SNP) | VAF 27/31 reads (87%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.819); catalogued as rs1372636669, COSV52091458; called by muse, mutect2, varscan2
- CDK5RAP2 | c.4903C>T p.L1635F | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.694); catalogued as COSV62572977; called by muse, mutect2, varscan2
- CDK9 | c.604G>A p.G202R | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs770506343, COSV64723556; called by muse, mutect2, varscan2
- CDON | c.1664C>T p.P555L | Missense Mutation (SNP) | VAF 44/97 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.359); catalogued as rs143213791; called by muse, mutect2, varscan2
- CDR2 | c.740C>T p.A247V | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as rs200274411, COSV51677628; called by muse, mutect2, varscan2
- CDRT15 | c.110T>C p.L37P | Missense Mutation (SNP) | VAF 45/131 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.955); catalogued as COSV101415158; called by muse, mutect2, varscan2
- CDX2 | c.716C>T p.A239V | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV66829292; called by muse, mutect2, varscan2
- CDYL2 | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 18/124 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.922); catalogued as COSV73653925; called by muse, mutect2, varscan2
- CEBPZ | c.2885-3del | Splice Region (DEL) | VAF 108/223 reads (48%) | catalogued as rs375852685; called by mutect2, varscan2
- CELF1 | c.482C>T p.A161V | Missense Mutation (SNP) | VAF 54/134 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.072); catalogued as COSV60110685; called by muse, mutect2, varscan2
- CELSR1 | c.6460C>T p.R2154C | Missense Mutation (SNP) | VAF 27/59 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs371148961; called by muse, mutect2, varscan2
- CELSR2 | c.2237G>A p.R746H | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs202175893, COSV54768659; called by muse, mutect2, varscan2
- CEMIP | c.1687G>A p.G563S | Missense Mutation (SNP) | VAF 49/92 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs147046826; called by muse, mutect2, varscan2
- CENPC | c.848C>T p.A283V | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as rs766812204, COSV99894322; called by muse, mutect2, varscan2
- CEP126 | c.2179C>T p.P727S | Missense Mutation (SNP) | VAF 8/95 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.044); catalogued as COSV99681363; called by muse, mutect2
- CEP131 | c.2618G>A p.R873H (on ENST00000269392 / NM_001319228.2; = p.R870H on NM_014984.4) | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs771409290, COSV53951482; called by muse, mutect2, varscan2
- CEP192 | c.2866C>T p.R956C | Missense Mutation (SNP) | VAF 20/37 reads (54%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs770649147, COSV58061677; called by muse, mutect2, varscan2
- CEP192 | c.5429A>G p.D1810G | Missense Mutation (SNP) | VAF 49/115 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.612); catalogued as COSV58061688; called by muse, mutect2, varscan2
- CEP250 | c.1863+1G>T p.X621_splice | Splice Site (SNP) | VAF 8/33 reads (24%) | catalogued as COSV100699111; called by muse, mutect2, varscan2
- CEP290 | c.3218C>T p.A1073V | Missense Mutation (SNP) | VAF 64/144 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100469590; called by muse, mutect2, varscan2
- CERKL | c.1536G>T p.E512D (on ENST00000339098 / NM_001030311.2; = p.E486D on NM_201548.5) | Missense Mutation (SNP) | VAF 84/173 reads (49%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as COSV59205110; called by muse, mutect2, varscan2
- CERS5 | c.389G>T p.R130M | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV58188712; called by muse, mutect2, varscan2
- CFAP43 | c.3373G>T p.G1125* | Nonsense Mutation (SNP) | VAF 47/103 reads (46%) | catalogued as COSV63852482; called by muse, mutect2, varscan2
- CFAP43 | c.3118C>T p.R1040C | Missense Mutation (SNP) | VAF 24/52 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs756724258, COSV53377045; called by muse, mutect2, varscan2
- CFAP52 | c.946C>T p.R316C | Missense Mutation (SNP) | VAF 29/70 reads (41%) | SIFT tolerated (0.08); PolyPhen benign (0.017); catalogued as rs1361072712, COSV55343747; called by muse, mutect2, varscan2
- CFAP58 | c.142G>A p.A48T | Missense Mutation (SNP) | VAF 39/68 reads (57%) | SIFT tolerated (0.59); PolyPhen benign (0.001); catalogued as COSV57211628; called by muse, mutect2, varscan2
- CFAP65 | c.543G>C p.R181S | Missense Mutation (SNP) | VAF 76/176 reads (43%) | SIFT tolerated (0.1); PolyPhen benign (0.375); catalogued as COSV99838419; called by muse, mutect2, varscan2
- CGNL1 | c.2602A>G p.K868E | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as COSV55565052; called by muse, mutect2, varscan2
- CHAT | c.965G>A p.R322H | Missense Mutation (SNP) | VAF 27/72 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.026); catalogued as rs906626657, COSV60322032, COSV60327752; called by muse, mutect2, varscan2
- CHD7 | c.313T>C p.Y105H | Missense Mutation (SNP) | VAF 35/83 reads (42%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.795); catalogued as COSV101418389; called by muse, mutect2, varscan2
- CHD9 | c.1219G>A p.E407K | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.017); catalogued as rs147266259, COSV68297015; called by muse, mutect2, varscan2
- CHD9 | c.2570G>A p.G857D | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.569); catalogued as rs371384628; called by muse, mutect2, varscan2
- CHKB | c.1114-1G>T p.X372_splice | Splice Site (SNP) | VAF 29/71 reads (41%) | catalogued as COSV56415800; called by muse, mutect2, varscan2
- CHMP1A | c.224A>C p.K75T | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.516); catalogued as COSV53682454; called by muse, mutect2, varscan2
- CHRDL2 | c.397C>T p.R133C | Missense Mutation (SNP) | VAF 55/127 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs1215037268, COSV55221854, COSV55222110; called by muse, mutect2, varscan2
- CHST3 | c.553G>A p.A185T | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.757); catalogued as rs768518290, COSV64150661; called by muse, mutect2, varscan2
- CHST5 | c.640G>A p.A214T | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT tolerated (0.11); PolyPhen benign (0.063); catalogued as rs753635982, COSV60341307; called by muse, mutect2, varscan2
- CHSY3 | c.1130G>T p.G377V | Missense Mutation (SNP) | VAF 40/79 reads (51%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.472); catalogued as COSV59274163; called by muse, mutect2, varscan2
- CIITA | c.1541C>T p.T514M | Missense Mutation (SNP) | VAF 14/20 reads (70%) | SIFT deleterious (0.05); PolyPhen benign (0.117); catalogued as rs1225897582, COSV60855236; called by muse, mutect2, varscan2
- CKAP2 | c.374A>T p.N125I (on ENST00000378037 / NM_001098525.2; = p.N124I on NM_018204.5) | Missense Mutation (SNP) | VAF 14/132 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV51621343; called by muse, mutect2, varscan2
- CLASP1 | c.95C>A p.S32* | Nonsense Mutation (SNP) | VAF 65/136 reads (48%) | catalogued as COSV55317970; called by muse, mutect2, varscan2
- CLDN19 | c.548G>A p.C183Y | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV56417404; called by muse, mutect2, varscan2
- CLDN5 | c.59del p.G20Vfs*2 (on ENST00000618236 / NM_001363066.2; = p.G105Vfs*2 on NM_003277.4) | Frame Shift Del (DEL) | VAF 23/67 reads (34%) | catalogued as rs768198935; called by mutect2, pindel, varscan2
- CLN6 | c.535T>C p.C179R | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.1); catalogued as COSV51116500; called by muse, mutect2, varscan2
- CLRN3 | c.623G>A p.R208Q | Missense Mutation (SNP) | VAF 40/95 reads (42%) | SIFT tolerated (0.45); PolyPhen benign (0.001); catalogued as rs371220164; called by muse, mutect2, varscan2
- CLSTN3 | c.2858del p.P953Hfs*106 | Frame Shift Del (DEL) | VAF 21/46 reads (46%) | catalogued as rs758841384; called by mutect2, pindel, varscan2
- CLVS2 | c.325G>A p.A109T | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as COSV51559773; called by muse, mutect2, varscan2
- CMIP | c.1947C>T p.D649= (on ENST00000537098 / NM_198390.2; = p.D555= on NM_030629.3) | Splice Region (SNP) | VAF 9/24 reads (38%) | catalogued as rs781781212, COSV67697583; called by muse, mutect2, varscan2
- CMTR1 | c.1898G>A p.R633Q | Missense Mutation (SNP) | VAF 36/67 reads (54%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.75); catalogued as rs1204927438, COSV65089838; called by muse, mutect2, varscan2
- CNNM1 | c.1519C>T p.H507Y | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.22); catalogued as COSV63200933; called by muse, mutect2, varscan2
- CNNM3 | c.1526A>G p.D509G | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as COSV59708905; called by muse, mutect2, varscan2
- CNOT1 | c.2706del p.Q904Sfs*9 | Frame Shift Del (DEL) | VAF 51/147 reads (35%) | catalogued as rs1397135931, COSV55313852; called by mutect2, pindel, varscan2
- CNTN4 | c.1232C>A p.T411K | Missense Mutation (SNP) | VAF 28/73 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.216); catalogued as COSV100639594; called by muse, varscan2
- CNTNAP2 | c.2099-1G>T p.X700_splice | Splice Site (SNP) | VAF 30/84 reads (36%) | catalogued as COSV62158224; called by muse, mutect2, varscan2
- CNTNAP5 | c.363A>T p.K121N | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.005); catalogued as COSV70478704; called by muse, mutect2, varscan2
- COBL | c.3665C>T p.T1222M | Missense Mutation (SNP) | VAF 28/67 reads (42%) | SIFT tolerated (0.1); PolyPhen benign (0.015); catalogued as rs201212787, COSV54341294; called by muse, mutect2, varscan2
- COL11A1 | c.1006G>T p.E336* | Nonsense Mutation (SNP) | VAF 35/93 reads (38%) | catalogued as COSV100614907, COSV62176520, COSV62184186; called by muse, mutect2, varscan2
- COL22A1 | c.4663C>T p.R1555* | Nonsense Mutation (SNP) | VAF 11/21 reads (52%) | catalogued as rs781131250, COSV57329251; called by muse, mutect2, varscan2
- COL4A2 | c.2398G>A p.G800R | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs867981304, COSV64626329; called by muse, mutect2, varscan2
- COL4A2 | c.3024A>C p.K1008N | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV64626335; called by muse, mutect2, varscan2
- COL4A5 | c.3924G>T p.Q1308H | Missense Mutation (SNP) | VAF 34/38 reads (89%) | SIFT deleterious (0.02); PolyPhen benign (0.333); catalogued as CM109090, COSV60358473; called by muse, mutect2, varscan2
- COL5A3 | c.637G>A p.A213T | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1218935816, COSV99319591; called by muse, mutect2, varscan2
- COL6A2 | c.385C>T p.R129C | Missense Mutation (SNP) | VAF 33/73 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.877); catalogued as rs374805550; called by muse, mutect2, varscan2
- COL6A3 | c.6931G>A p.G2311R | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM1310906, COSV55083802; called by muse, mutect2, varscan2
- COL7A1 | c.6691C>A p.P2231T | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.972); catalogued as rs369838476, COSV100097369, COSV60393249; called by muse, mutect2, varscan2
- COPA | c.2754+2T>C p.X918_splice | Splice Site (SNP) | VAF 51/139 reads (37%) | catalogued as COSV99616591; called by muse, mutect2, varscan2
- COPS3 | c.967G>A p.A323T | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV52004656; called by muse, mutect2, varscan2
- COX4I1 | c.206_208del p.S69del | In Frame Del (DEL) | VAF 12/37 reads (32%) | catalogued as rs1567843713; called by pindel, varscan2
- CPA1 | c.847G>A p.E283K | Missense Mutation (SNP) | VAF 27/67 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs782561684, CM139187, COSV50568458; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CPAMD8 | c.4762G>A p.D1588N (on ENST00000651564; = p.D1541N on NM_015692.5) | Missense Mutation (SNP) | VAF 26/71 reads (37%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.969); catalogued as rs778890173, COSV71597596; called by muse, mutect2
- CPD | c.2669G>C p.S890T | Missense Mutation (SNP) | VAF 51/121 reads (42%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV56711612; called by muse, mutect2, varscan2
- CPNE3 | c.1093T>G p.F365V | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV52204979; called by muse, mutect2, varscan2
- CPNE7 | c.1589A>G p.E530G | Missense Mutation (SNP) | VAF 30/56 reads (54%) | SIFT deleterious (0.02); PolyPhen benign (0.142); catalogued as COSV52011615; called by muse, mutect2, varscan2
- CPS1 | c.4358G>A p.R1453Q | Missense Mutation (SNP) | VAF 48/230 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1559142152, CM104560, COSV51805267; called by muse, mutect2, varscan2
- CPT1A | c.530C>A p.P177Q | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55754132; called by muse, mutect2, varscan2
- CPT1B | c.2186A>G p.E729G | Missense Mutation (SNP) | VAF 31/70 reads (44%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.582); catalogued as COSV56415794; called by muse, mutect2, varscan2
- CRACD | c.1733C>A p.A578D | Missense Mutation (SNP) | VAF 11/18 reads (61%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.796); catalogued as COSV99073093; called by muse, mutect2, varscan2
- CRACD | c.3156A>C p.K1052N | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); catalogued as COSV99949873; called by muse, mutect2, varscan2
- CREB3L4 | c.809_811del p.N270del | In Frame Del (DEL) | VAF 10/36 reads (28%) | catalogued as rs760103702; called by pindel, varscan2
- CRIM1 | c.34G>A p.G12S | Missense Mutation (SNP) | VAF 28/48 reads (58%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.108); catalogued as COSV54861111; called by muse, mutect2, varscan2
- CRISP2 | c.56C>T p.A19V | Missense Mutation (SNP) | VAF 26/66 reads (39%) | SIFT tolerated (0.15); PolyPhen benign (0.1); catalogued as COSV59253828; called by muse, mutect2, varscan2
- CROCC | c.3781G>A p.A1261T | Missense Mutation (SNP) | VAF 65/139 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.703); catalogued as rs1421717237, COSV65010958; called by muse, varscan2
- CROCC | c.3797C>T p.T1266I | Missense Mutation (SNP) | VAF 61/142 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.052); catalogued as COSV65010966; called by muse, varscan2
- CRX | c.434C>A p.P145H | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.712); catalogued as COSV55757103; called by muse, mutect2, varscan2
- CRYBG2 | c.3623C>T p.S1208F | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1255193027, COSV57484600; called by muse, mutect2, varscan2
- CRYBG2 | c.3622T>G p.S1208A | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100366928; called by muse, mutect2, varscan2
- CSMD3 | c.8722C>T p.Q2908* (on ENST00000297405 / NM_001363185.1; = p.Q2739* on NM_052900.3) | Nonsense Mutation (SNP) | VAF 52/152 reads (34%) | catalogued as COSV52133217, COSV52177711; called by muse, mutect2, varscan2
- CSMD3 | c.8419G>A p.E2807K (on ENST00000297405 / NM_001363185.1; = p.E2638K on NM_052900.3) | Missense Mutation (SNP) | VAF 28/68 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.006); catalogued as rs765143806, COSV52133249; called by muse, mutect2, varscan2
- CSN3 | c.289C>T p.Q97* | Nonsense Mutation (SNP) | VAF 34/81 reads (42%) | catalogued as COSV59243746; called by muse, mutect2, varscan2
- CSPG4 | c.1081A>G p.N361D | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.71); catalogued as COSV57892573; called by muse, mutect2, varscan2
- CTNNA1 | c.727C>A p.L243M | Missense Mutation (SNP) | VAF 67/149 reads (45%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.511); catalogued as COSV57071278; called by muse, mutect2, varscan2
- CTNND2 | c.256G>A p.G86R | Missense Mutation (SNP) | VAF 31/85 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.753); catalogued as rs763519304, COSV58866245; called by muse, mutect2, varscan2
- CTRB1 | c.766G>A p.V256M | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.777); catalogued as COSV50779696; called by muse, mutect2, varscan2
- CUL2 | c.1325G>A p.R442H | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66078682; called by muse, mutect2, varscan2
- CXorf56 | c.287C>T p.P96L (on ENST00000536133 / NM_001170570.2; = p.P110L on NM_022101.4) | Missense Mutation (SNP) | VAF 50/54 reads (93%) | SIFT tolerated (0.11); PolyPhen benign (0.029); catalogued as rs1271493964, COSV57437895; called by muse, mutect2, varscan2
- CYC1 | c.276del p.S93Afs*161 | Frame Shift Del (DEL) | VAF 11/29 reads (38%) | catalogued as rs756254049; called by mutect2, pindel, varscan2
- CYLC1 | c.1185C>A p.D395E | Missense Mutation (SNP) | VAF 52/66 reads (79%) | SIFT deleterious (0.03); PolyPhen benign (0.029); catalogued as COSV61410888; called by muse, mutect2, varscan2
- CYP24A1 | c.1163C>T p.T388M | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as rs571886397, COSV53773343; called by muse, mutect2, varscan2
- CYP2A6 | c.495C>T p.G165= | Splice Region (SNP) | VAF 54/146 reads (37%) | catalogued as COSV56534421; called by muse, varscan2
- CYP2D6 | c.1114del p.L372Wfs*3 | Frame Shift Del (DEL) | VAF 35/94 reads (37%) | catalogued as COSV100637313; called by mutect2, varscan2
- CYP46A1 | c.771G>T p.W257C | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.025); catalogued as COSV99952812; called by muse, mutect2, varscan2
- CYTH2 | c.104G>A p.R35H | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.977); catalogued as COSV57310175; called by muse, mutect2, varscan2
- DAO | c.34G>A p.G12R | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs373913310, COSV57321201; called by muse, mutect2, varscan2
- DCAF6 | c.1657G>T p.G553* (on ENST00000312263 / NM_001349778.1; = p.G573* on NM_018442.3 and 4 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 87/183 reads (48%) | catalogued as COSV56576464; called by muse, mutect2, varscan2
- DCDC1 | c.5053T>C p.W1685R (on ENST00000597505 / NM_001367979.1; = p.W792R on NM_020869.3) | Missense Mutation (SNP) | VAF 80/173 reads (46%) | SIFT tolerated (0.12); PolyPhen benign (0.015); catalogued as COSV57998162; called by muse, mutect2, varscan2
- DCLRE1A | c.610G>T p.G204C | Missense Mutation (SNP) | VAF 31/76 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.72); catalogued as COSV63748356; called by muse, mutect2, varscan2
- DCTN1 | c.2967G>T p.E989D | Missense Mutation (SNP) | VAF 26/66 reads (39%) | SIFT tolerated (0.83); PolyPhen benign (0.003); catalogued as COSV62619916; called by muse, mutect2, varscan2
- DDR2 | c.1892G>A p.R631Q | Missense Mutation (SNP) | VAF 38/80 reads (48%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.937); catalogued as rs779963287, COSV63370061; called by muse, mutect2, varscan2
- DDX1 | c.1757A>G p.Y586C | Missense Mutation (SNP) | VAF 16/164 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV51838753; called by muse, mutect2
- DDX17 | c.362del p.K121Sfs*4 | Frame Shift Del (DEL) | VAF 20/38 reads (53%) | catalogued as rs759023106; called by mutect2, varscan2
- DEGS2 | c.125G>A p.R42H | Missense Mutation (SNP) | VAF 23/49 reads (47%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as rs1027588359, COSV59783765; called by muse, mutect2, varscan2
- DENND1C | c.491del p.P164Lfs*29 | Frame Shift Del (DEL) | VAF 6/14 reads (43%) | catalogued as rs553532837; called by mutect2, varscan2
- DENND2A | c.2800C>T p.R934C | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.329); catalogued as rs1185495323, COSV52050299, COSV99326827; called by muse, mutect2
- DENND4B | c.787C>T p.L263F | Missense Mutation (SNP) | VAF 27/69 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1218010520, COSV63409417; called by muse, mutect2, varscan2
- DES | c.639+1G>A p.X213_splice | Splice Site (SNP) | VAF 50/109 reads (46%) | catalogued as rs868785776, COSV64660019; called by muse, mutect2, varscan2
- DES | c.710C>T p.A237V | Missense Mutation (SNP) | VAF 17/34 reads (50%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.498); catalogued as rs374144840; called by muse, mutect2, varscan2
- DHX33 | c.434C>T p.T145I | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.459); catalogued as COSV99834490; called by muse, mutect2, varscan2
- DIO2 | c.518C>T p.P173L | Missense Mutation (SNP) | VAF 21/38 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV101375955; called by muse, mutect2, varscan2
- DISP3 | c.2330G>A p.S777N | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53823439; called by muse, mutect2, varscan2
- DLL4 | c.1013G>A p.S338N | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.856); catalogued as COSV51061351; called by muse, mutect2, varscan2
- DMD | c.7873-1G>T p.X2625_splice | Splice Site (SNP) | VAF 48/56 reads (86%) | catalogued as COSV58899027; called by muse, mutect2, varscan2
- DMRT2 | c.755G>T p.R252I | Missense Mutation (SNP) | VAF 28/74 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52400881, COSV52401282; called by muse, mutect2, varscan2
- DMXL1 | c.5004del p.F1668Lfs*15 | Frame Shift Del (DEL) | VAF 71/202 reads (35%) | catalogued as rs770333963; called by mutect2, pindel, varscan2
- DNAH1 | c.7673T>C p.L2558P | Missense Mutation (SNP) | VAF 50/119 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1490295686, COSV70227382; called by muse, mutect2, varscan2
- DNAH1 | c.11966A>T p.E3989V | Missense Mutation (SNP) | VAF 29/71 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.039); catalogued as COSV56232158; called by muse, mutect2, varscan2
- DNAH17 | c.8992G>A p.V2998I | Missense Mutation (SNP) | VAF 23/202 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.567); catalogued as rs569441390, COSV67751289; called by muse, mutect2, varscan2
- DNAH17 | c.1543T>C p.C515R | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.748); catalogued as COSV67751291; called by muse, mutect2, varscan2
- DNAH2 | c.3160C>A p.L1054M | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT tolerated (0.55); PolyPhen benign (0.041); catalogued as COSV66717837; called by muse, mutect2, varscan2
- DNAH2 | c.5581A>G p.N1861D | Missense Mutation (SNP) | VAF 59/130 reads (45%) | SIFT tolerated (0.12); PolyPhen benign (0.398); catalogued as COSV66717841; called by muse, mutect2, varscan2
- DNAH3 | c.1852G>T p.D618Y | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV54507210, COSV54510704; called by muse, mutect2, varscan2
- DNAH8 | c.9375G>T p.E3125D | Missense Mutation (SNP) | VAF 129/285 reads (45%) | SIFT tolerated (0.24); PolyPhen benign (0.181); catalogued as COSV59425945; called by muse, mutect2, varscan2
- DNAI1 | c.1468G>T p.G490W | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.374); catalogued as COSV54279714; called by muse, mutect2, varscan2
- DNAJB11 | c.70C>T p.R24* | Nonsense Mutation (SNP) | VAF 19/41 reads (46%) | catalogued as COSV54002207; called by muse, mutect2, varscan2
- DNAJB13 | c.475del p.I159Lfs*8 | Frame Shift Del (DEL) | VAF 10/24 reads (42%) | catalogued as rs754363435; called by mutect2, pindel, varscan2
- DNAJC3 | c.502G>A p.G168R | Missense Mutation (SNP) | VAF 39/112 reads (35%) | SIFT tolerated (0.39); PolyPhen benign (0.013); catalogued as COSV65130890; called by muse, mutect2, varscan2
- DNASE1 | c.321-1G>T p.X107_splice | Splice Site (SNP) | VAF 28/56 reads (50%) | catalogued as COSV55912859; called by muse, mutect2, varscan2
- DNHD1 | c.13579G>A p.A4527T | Missense Mutation (SNP) | VAF 9/15 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54432266; called by muse, mutect2, varscan2
- DNM1 | c.307G>A p.A103T | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT tolerated (0.18); PolyPhen benign (0.005); catalogued as COSV100360272; called by muse, mutect2, varscan2
- DNTTIP2 | c.1976del p.N659Mfs*6 | Frame Shift Del (DEL) | VAF 79/222 reads (36%) | catalogued as rs1348666454; called by mutect2, pindel, varscan2
- DOCK2 | c.3212G>A p.R1071H | Missense Mutation (SNP) | VAF 57/140 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs750051021, COSV56948722; called by muse, mutect2
- DOP1B | c.3241C>T p.R1081* | Nonsense Mutation (SNP) | VAF 22/55 reads (40%) | catalogued as rs766473651, COSV67692310; called by muse, mutect2, varscan2
- DPPA4 | c.41C>T p.A14V | Missense Mutation (SNP) | VAF 37/69 reads (54%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV59509717; called by muse, mutect2, varscan2
- DPYSL5 | c.235G>A p.V79M | Missense Mutation (SNP) | VAF 66/166 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.027); catalogued as rs751893055, COSV56509996; called by muse, mutect2, varscan2
- DRAP1 | c.179G>A p.R60Q | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV56988187; called by muse, mutect2, varscan2
- DROSHA | c.927del p.E310Sfs*42 | Frame Shift Del (DEL) | VAF 35/99 reads (35%) | catalogued as COSV60781939; called by mutect2, pindel, varscan2
- DSTYK | c.2207G>A p.R736Q | Missense Mutation (SNP) | VAF 34/68 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.327); catalogued as rs755781145, COSV65686770; called by muse, mutect2, varscan2
- DTD1 | c.583G>A p.A195T | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.006); catalogued as rs754144369, COSV66278536; called by muse, mutect2, varscan2
- DUOX2 | c.161-1G>T p.X54_splice | Splice Site (SNP) | VAF 9/46 reads (20%) | catalogued as COSV99973457; called by muse, mutect2, varscan2
- DYNC1H1 | c.7175A>G p.D2392G | Missense Mutation (SNP) | VAF 52/125 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs1439899908, COSV100795289; called by muse, mutect2, varscan2
- DYNC1I2 | c.1351A>G p.S451G | Missense Mutation (SNP) | VAF 101/224 reads (45%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as COSV55524991; called by muse, mutect2, varscan2
- DYNC2H1 | c.12677G>T p.S4226I | Missense Mutation (SNP) | VAF 76/173 reads (44%) | SIFT tolerated (0.13); PolyPhen benign (0.093); catalogued as COSV62089627; called by muse, mutect2, varscan2
- E2F7 | c.694G>A p.E232K | Missense Mutation (SNP) | VAF 16/235 reads (7%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.613); catalogued as rs1378275288, COSV100523805; called by muse, mutect2
- E4F1 | c.1339G>A p.A447T | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.829); catalogued as COSV57038244; called by muse, mutect2, varscan2
- EBPL | c.479G>A p.S160N | Missense Mutation (SNP) | VAF 49/117 reads (42%) | SIFT tolerated (0.26); PolyPhen benign (0.028); catalogued as COSV54431829; called by muse, mutect2, varscan2
- ECHS1 | c.531G>T p.Q177H | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.902); catalogued as COSV63906673; called by muse, mutect2, varscan2
- ECPAS | c.197G>A p.R66H | Missense Mutation (SNP) | VAF 141/316 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as rs372926033; called by muse, mutect2, varscan2
- EEF1AKNMT | c.527G>A p.R176Q (on ENST00000361735 / NM_015935.5; = p.R90Q on NM_014955.3) | Missense Mutation (SNP) | VAF 17/33 reads (52%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs749473716, COSV62282711; called by muse, mutect2, varscan2
- EEF2K | c.331C>T p.R111C | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs747658944, COSV53779724; called by muse, mutect2, varscan2
- EGFLAM | c.1097del p.G366Afs*32 | Frame Shift Del (DEL) | VAF 24/53 reads (45%) | catalogued as rs773311790; called by mutect2, pindel, varscan2
- EGR2 | c.833C>T p.A278V | Missense Mutation (SNP) | VAF 23/46 reads (50%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as COSV54346459; called by muse, mutect2, varscan2
- EHD4 | c.1034T>C p.L345P | Missense Mutation (SNP) | VAF 59/131 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as COSV55003893; called by muse, mutect2, varscan2
- EIF3D | c.289C>T p.R97* | Nonsense Mutation (SNP) | VAF 27/66 reads (41%) | catalogued as COSV53403032; called by muse, mutect2, varscan2
- EIF3I | c.898A>G p.S300G (on ENST00000373586; = p.S302G on NM_003757.3) | Missense Mutation (SNP) | VAF 25/56 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); catalogued as COSV61889834; called by muse, mutect2, varscan2
- EIF4ENIF1 | c.2711G>A p.R904H | Missense Mutation (SNP) | VAF 25/58 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs755466322, COSV57515176; called by muse, mutect2, varscan2
- EIF4ENIF1 | c.2240C>T p.A747V | Missense Mutation (SNP) | VAF 103/249 reads (41%) | SIFT tolerated (0.62); PolyPhen benign (0.024); catalogued as COSV57515183; called by muse, mutect2, varscan2
- EIF5B | c.2551G>A p.A851T | Missense Mutation (SNP) | VAF 85/194 reads (44%) | SIFT tolerated (0.38); PolyPhen benign (0.147); catalogued as COSV56811792; called by muse, mutect2, varscan2
- ELL3 | c.944G>A p.R315H | Missense Mutation (SNP) | VAF 26/189 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs371545209; called by muse, mutect2, varscan2
- ELMOD1 | c.64C>T p.R22C | Missense Mutation (SNP) | VAF 53/119 reads (45%) | SIFT tolerated (0.18); PolyPhen benign (0.072); catalogued as rs201382091; called by muse, mutect2, varscan2
- ELOA | c.1394del p.N465Mfs*19 | Frame Shift Del (DEL) | VAF 49/92 reads (53%) | catalogued as rs766700925; called by mutect2, varscan2
- EMD | c.661C>T p.R221C | Missense Mutation (SNP) | VAF 47/54 reads (87%) | SIFT deleterious (0); PolyPhen benign (0.441); catalogued as rs1434136213, COSV63962066; called by muse, mutect2, varscan2
- EMILIN3 | c.1380del p.W461Gfs*21 | Frame Shift Del (DEL) | VAF 9/69 reads (13%) | catalogued as rs759858342; called by pindel, varscan2*
- EML4 | c.387del p.E130Rfs*43 | Frame Shift Del (DEL) | VAF 20/48 reads (42%) | catalogued as rs770453803; called by mutect2, varscan2
- EMSY | c.2030C>T p.A677V | Missense Mutation (SNP) | VAF 55/142 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.403); catalogued as COSV58258444; called by muse, mutect2, varscan2
- ENKD1 | c.259G>T p.G87C | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV54675539; called by muse, mutect2, varscan2
- ENPP5 | c.1220T>A p.V407D | Missense Mutation (SNP) | VAF 33/90 reads (37%) | SIFT tolerated (0.49); PolyPhen benign (0.054); catalogued as COSV57908323; called by muse, mutect2, varscan2
- ENTPD4 | c.1756C>T p.R586W | Missense Mutation (SNP) | VAF 9/15 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs375242682; called by muse, mutect2, varscan2
- EP300 | c.6772C>T p.Q2258* | Nonsense Mutation (SNP) | VAF 21/47 reads (45%) | catalogued as COSV54329314; called by muse, mutect2, varscan2
- EPHA10 | c.2468T>A p.F823Y | Missense Mutation (SNP) | VAF 44/93 reads (47%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as COSV57622049; called by muse, mutect2, varscan2
- EPHA3 | c.2147C>T p.A716V | Missense Mutation (SNP) | VAF 33/67 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV60698575; called by muse, mutect2, varscan2
- EPHA4 | c.2350G>T p.G784C | Missense Mutation (SNP) | VAF 28/63 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV56028983; called by muse, mutect2, varscan2
- EPHA8 | c.2348G>A p.R783Q | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs750373572, COSV51264874; called by muse, mutect2, varscan2
- EPN2 | c.755G>A p.R252H | Missense Mutation (SNP) | VAF 52/128 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.063); catalogued as rs567144915, COSV59060450; called by muse, mutect2, varscan2
- ERAP1 | c.1867C>A p.L623I | Missense Mutation (SNP) | VAF 52/109 reads (48%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.893); catalogued as COSV57086187; called by muse, mutect2, varscan2
- ERAP1 | c.1685T>G p.L562R | Missense Mutation (SNP) | VAF 36/85 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV57086197; called by muse, mutect2, varscan2
- ERCC1 | c.700C>T p.R234W | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.724); catalogued as rs772941786, COSV50003866; called by muse, mutect2, varscan2
- ERGIC3 | c.874G>A p.G292R | Missense Mutation (SNP) | VAF 40/70 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs745424936, COSV53413931, COSV53414430; called by muse, mutect2, varscan2
- ERICH3 | c.2231A>G p.N744S | Missense Mutation (SNP) | VAF 56/148 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.359); catalogued as COSV58602273; called by muse, varscan2
- ERMARD | c.1295C>T p.P432L | Missense Mutation (SNP) | VAF 48/107 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs375856725; called by muse, mutect2, varscan2
- ERO1B | c.155T>C p.F52S | Missense Mutation (SNP) | VAF 144/318 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV59241906; called by muse, mutect2, varscan2
- ETV5 | c.1451C>T p.T484I | Missense Mutation (SNP) | VAF 26/115 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.521); catalogued as COSV60500483; called by muse, mutect2, varscan2
- EVI5 | c.1222dup p.M408Nfs*5 | Frame Shift Ins (INS) | VAF 20/42 reads (48%) | catalogued as rs760182064; called by mutect2, varscan2
- EVX2 | c.286G>A p.A96T | Missense Mutation (SNP) | VAF 26/57 reads (46%) | SIFT tolerated (0.28); PolyPhen benign (0.009); catalogued as rs1379226242, COSV57962786; called by muse, mutect2, varscan2
- EXOSC3 | c.806_808del p.F269del | In Frame Del (DEL) | VAF 56/128 reads (44%) | catalogued as rs765457042; called by pindel, varscan2
- F8 | c.3870del p.E1292Rfs*16 | Frame Shift Del (DEL) | VAF 84/100 reads (84%) | catalogued as rs1426645898, CD022147, CD0911173, COSV64270790; called by mutect2, varscan2
- FAM102A | c.62T>C p.L21P | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66193504; called by muse, mutect2, varscan2
- FAM135B | c.2560C>G p.Q854E | Missense Mutation (SNP) | VAF 28/72 reads (39%) | SIFT tolerated (0.39); PolyPhen benign (0.018); catalogued as COSV52711209, COSV52713195, COSV99423862; called by muse, mutect2, varscan2
- FAM13A | c.289G>A p.E97K | Missense Mutation (SNP) | VAF 33/77 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs752786659, COSV51999272; called by muse, mutect2, varscan2
- FAM155B | c.907C>A p.Q303K | Missense Mutation (SNP) | VAF 45/49 reads (92%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.519); catalogued as COSV52935574; called by muse, mutect2, varscan2
- FAM171B | c.1571G>A p.R524H | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs779066655, COSV59001734; called by muse, mutect2, varscan2
- FAM20B | c.274G>A p.A92T | Missense Mutation (SNP) | VAF 34/81 reads (42%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV55379664; called by muse, mutect2, varscan2
- FAM210A | c.13G>A p.V5I | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.001); catalogued as rs779671314, COSV59183726; called by mutect2, varscan2
- FAM217A | c.746C>A p.P249H | Missense Mutation (SNP) | VAF 64/170 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV51159267; called by muse, mutect2, varscan2
- FAM241B | c.316C>A p.L106I | Missense Mutation (SNP) | VAF 55/125 reads (44%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.986); catalogued as COSV64768111; called by muse, mutect2, varscan2
- FAM50B | c.314G>A p.R105Q | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT tolerated (0.13); PolyPhen benign (0.227); catalogued as rs770945816, COSV66654639; called by muse, mutect2, varscan2
- FAM83E | c.1231C>T p.R411W | Missense Mutation (SNP) | VAF 31/52 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs370573825; called by muse, mutect2, varscan2
- FAM91A1 | c.1831G>T p.G611* | Nonsense Mutation (SNP) | VAF 71/145 reads (49%) | catalogued as COSV58236268; called by muse, mutect2, varscan2
- FAM98A | c.998C>G p.T333R | Missense Mutation (SNP) | VAF 25/53 reads (47%) | SIFT tolerated (0.56); PolyPhen benign (0.022); catalogued as COSV53209709; called by muse, mutect2, varscan2
- FAM9A | c.387G>T p.K129N | Missense Mutation (SNP) | VAF 107/122 reads (88%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.034); catalogued as COSV101121367; called by muse, mutect2, varscan2
- FAN1 | c.2270C>T p.P757L | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.225); catalogued as rs56258078, COSV62950094; called by muse, mutect2, varscan2
- FANCA | c.643_644del p.C215Lfs*4 | Frame Shift Del (DEL) | VAF 30/92 reads (33%) | catalogued as rs1338138752; called by pindel, varscan2
- FANCM | c.5912A>G p.E1971G | Missense Mutation (SNP) | VAF 35/83 reads (42%) | SIFT tolerated (0.05); PolyPhen benign (0.006); catalogued as COSV57498605; called by muse, mutect2, varscan2
- FAR2 | c.1329del p.K443Nfs*4 | Frame Shift Del (DEL) | VAF 34/75 reads (45%) | catalogued as COSV99479542; called by mutect2, pindel, varscan2
- FARP2 | c.1315A>G p.S439G | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT tolerated (0.2); PolyPhen benign (0.015); catalogued as COSV50869913; called by muse, mutect2, varscan2
- FASN | c.1925G>A p.C642Y | Missense Mutation (SNP) | VAF 28/49 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60751960; called by muse, mutect2, varscan2
- FAT2 | c.6544G>T p.E2182* | Nonsense Mutation (SNP) | VAF 12/36 reads (33%) | catalogued as COSV55815833; called by muse, mutect2, varscan2
- FAT2 | c.251C>T p.T84I | Missense Mutation (SNP) | VAF 59/138 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV55815841; called by muse, mutect2, varscan2
- FAT3 | c.12527G>A p.R4176H | Missense Mutation (SNP) | VAF 24/46 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1266155564, COSV53089795; called by muse, mutect2, varscan2
- FAT4 | c.9328G>A p.V3110I | Missense Mutation (SNP) | VAF 42/100 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as COSV100629799; called by muse, mutect2, varscan2
- FAT4 | c.10666G>A p.A3556T | Missense Mutation (SNP) | VAF 46/119 reads (39%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.997); catalogued as rs1276011786, COSV58676438; called by muse, mutect2, varscan2
- FBN3 | c.2259del p.G754Afs*23 | Frame Shift Del (DEL) | VAF 17/41 reads (41%) | catalogued as COSV54456788; called by mutect2, pindel, varscan2
- FBXO30 | c.74G>A p.G25E | Missense Mutation (SNP) | VAF 37/84 reads (44%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.862); catalogued as COSV52790600; called by muse, mutect2, varscan2
- FBXW2 | c.863C>A p.P288H | Missense Mutation (SNP) | VAF 28/63 reads (44%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.99); catalogued as COSV61596652; called by muse, mutect2, varscan2
- FBXW7 | c.277G>T p.G93* | Nonsense Mutation (SNP) | VAF 90/213 reads (42%) | catalogued as COSV55902829; called by muse, mutect2, varscan2
- FDXACB1 | c.1226A>G p.Q409R | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV52787611; called by muse, mutect2, varscan2
- FDXR | c.151T>G p.F51V | Missense Mutation (SNP) | VAF 30/63 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.681); catalogued as rs1312462458, COSV53120751; called by muse, mutect2, varscan2
- FES | c.427C>T p.R143* | Nonsense Mutation (SNP) | VAF 34/65 reads (52%) | catalogued as COSV51575494; called by muse, mutect2, varscan2
- FES | c.1933C>A p.L645M | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100183283; called by muse, mutect2
- FKBP5 | c.346G>A p.A116T | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs1320050124, COSV61880676; called by muse, mutect2, varscan2
- FKBP9 | c.384del p.N129Ifs*10 | Frame Shift Del (DEL) | VAF 62/116 reads (53%) | catalogued as rs752076602; called by mutect2, varscan2
- FLII | c.1295G>A p.R432K | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.015); catalogued as COSV100493795; called by muse, mutect2, varscan2
- FLNA | c.4903C>T p.R1635C | Missense Mutation (SNP) | VAF 28/31 reads (90%) | SIFT deleterious (0); PolyPhen possibly damaging (0.676); catalogued as rs1400230946, COSV61040067; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FLOT1 | c.1240G>A p.V414M | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs201200201; called by muse, mutect2, varscan2
- FLRT1 | c.865A>G p.T289A | Missense Mutation (SNP) | VAF 13/118 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV99735939; called by muse, mutect2, varscan2
- FOXB2 | c.112G>A p.D38N | Missense Mutation (SNP) | VAF 35/77 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs1005519950, COSV65022636; called by muse, mutect2, varscan2
- FOXD4L4 | c.170C>T p.P57L | Missense Mutation (SNP) | VAF 194/1003 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.585); catalogued as rs1458300125; called by muse, varscan2
- FOXI1 | c.421G>A p.D141N | Missense Mutation (SNP) | VAF 34/88 reads (39%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.872); catalogued as rs1438318544, COSV60388299; called by muse, mutect2, varscan2
- FOXN1 | c.813A>C p.K271N | Missense Mutation (SNP) | VAF 52/116 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.845); catalogued as COSV56880994; called by muse, mutect2, varscan2
- FOXR1 | c.355C>T p.R119W | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs782479317, COSV100393000; called by muse, mutect2, varscan2
- FRMD1 | c.640C>A p.P214T | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51960816; called by muse, mutect2, varscan2
- FRYL | c.6686T>A p.I2229N | Missense Mutation (SNP) | VAF 37/91 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.189); catalogued as COSV51942977; called by muse, mutect2, varscan2
- FSCN2 | c.416C>A p.P139Q | Missense Mutation (SNP) | VAF 16/28 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.812); catalogued as COSV58367119; called by muse, mutect2, varscan2
- FSIP2 | c.19171G>A p.A6391T | Missense Mutation (SNP) | VAF 70/176 reads (40%) | SIFT deleterious (0.05); PolyPhen benign (0.091); catalogued as COSV100556068; called by muse, mutect2, varscan2
- FURIN | c.779G>T p.G260V | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51575489; called by muse, mutect2, varscan2
- FUT7 | c.47G>T p.G16V | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV55799192; called by muse, mutect2, varscan2
- FZD10 | c.690G>A p.W230* | Nonsense Mutation (SNP) | VAF 27/58 reads (47%) | catalogued as COSV57472648; called by muse, mutect2, varscan2
- FZD8 | c.401G>A p.R134H | Missense Mutation (SNP) | VAF 36/78 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.804); catalogued as rs1376058430, COSV65967648, COSV65968519; called by muse, mutect2, varscan2
- G3BP1 | c.1109G>A p.R370H | Missense Mutation (SNP) | VAF 109/226 reads (48%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.877); catalogued as rs765135383, COSV62365819; called by muse, mutect2, varscan2
- GAB1 | c.50del p.P17Rfs*5 | Frame Shift Del (DEL) | VAF 33/107 reads (31%) | catalogued as rs755581817; called by mutect2, pindel, varscan2
- GAB4 | c.1216C>T p.H406Y | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT tolerated (0.34); PolyPhen benign (0.425); catalogued as COSV68753314; called by muse, mutect2, varscan2
- GABBR2 | c.1006C>T p.Q336* | Nonsense Mutation (SNP) | VAF 33/90 reads (37%) | catalogued as COSV52296908, COSV99411553; called by muse, mutect2, varscan2
- GABPA | c.1154A>G p.D385G | Missense Mutation (SNP) | VAF 83/200 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.725); catalogued as COSV61395755; called by muse, mutect2, varscan2
- GABRA5 | c.902C>T p.T301M | Missense Mutation (SNP) | VAF 17/28 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100165230, COSV59477223; called by muse, mutect2, varscan2
- GALNT17 | c.586G>A p.E196K | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.403); catalogued as COSV61150081, COSV61153484, COSV61171276; called by muse, mutect2, varscan2
- GALNT17 | c.1199G>A p.R400H | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1016356695, COSV61188664; called by muse, mutect2, varscan2
- GALNT17 | c.1390G>A p.V464I | Missense Mutation (SNP) | VAF 32/94 reads (34%) | SIFT tolerated (0.41); PolyPhen benign (0.001); catalogued as rs557986424, COSV61153495, COSV61165790; called by muse, mutect2, varscan2
- GAS6 | c.449dup p.R151Pfs*27 | Frame Shift Ins (INS) | VAF 8/22 reads (36%) | catalogued as rs773341392; called by mutect2, varscan2
- GATA4 | c.794G>A p.R265H | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs745533633, COSV58732831; called by muse, mutect2, varscan2
- GBF1 | c.3073C>T p.R1025W (on ENST00000369983 / NM_001377137.1; = p.R1024W on NM_004193.3) | Missense Mutation (SNP) | VAF 36/68 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs376621882; called by muse, mutect2, varscan2
- GCC2 | c.2135del p.L712Cfs*16 | Frame Shift Del (DEL) | VAF 78/199 reads (39%) | catalogued as rs777909420; called by mutect2, pindel, varscan2
- GDAP1L1 | c.1077C>G p.Y359* | Nonsense Mutation (SNP) | VAF 28/74 reads (38%) | catalogued as COSV100697664; called by muse, mutect2, varscan2
- GDF5 | c.150G>C p.R50S | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.034); catalogued as COSV65500243; called by muse, mutect2, varscan2
- GGT5 | c.1753G>T p.G585C | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54069250; called by muse, mutect2, varscan2
- GIGYF1 | c.2504G>A p.S835N | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.021); catalogued as COSV51940303; called by muse, mutect2, varscan2
- GINS2 | c.544T>C p.S182P | Missense Mutation (SNP) | VAF 58/121 reads (48%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.462); catalogued as COSV53670462; called by muse, mutect2, varscan2
- GIT2 | c.1592C>T p.A531V (on ENST00000355312 / NM_057169.5; = p.A483V on NM_014776.5) | Missense Mutation (SNP) | VAF 73/164 reads (45%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs1178882459, COSV58079350; called by muse, mutect2, varscan2
- GLA | c.239G>T p.G80V | Missense Mutation (SNP) | VAF 30/34 reads (88%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM160430, COSV54508542; called by muse, mutect2, varscan2
- GLB1L2 | c.1354C>T p.Q452* | Nonsense Mutation (SNP) | VAF 26/64 reads (41%) | catalogued as COSV60277982, COSV60278404; called by muse, mutect2, varscan2
- GLI3 | c.3697A>G p.N1233D | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0); catalogued as COSV101230005; called by muse, mutect2, varscan2
- GLI3 | c.935C>T p.T312M | Missense Mutation (SNP) | VAF 54/139 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs772929930, COSV67894711; ClinVar: benign; called by muse, mutect2, varscan2
- GLI3 | c.181C>T p.Q61* | Nonsense Mutation (SNP) | VAF 78/180 reads (43%) | catalogued as COSV67886534; called by muse, mutect2, varscan2
- GLRB | c.782C>T p.T261I | Missense Mutation (SNP) | VAF 14/113 reads (12%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.995); catalogued as COSV52414663; called by muse, mutect2, varscan2
- GMPPA | c.401G>A p.R134H | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs780869528, COSV58006343; called by muse, mutect2, varscan2
- GNAI2 | c.1055G>A p.C352Y | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.776); catalogued as COSV56493197; called by muse, mutect2, varscan2
- GNAS | c.887C>T p.T296M | Missense Mutation (SNP) | VAF 30/71 reads (42%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.003); catalogued as rs1568925561, COSV58327280; called by muse, mutect2, varscan2
- GNB3 | c.367A>G p.I123V | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT tolerated (0.7); PolyPhen benign (0.015); catalogued as rs782780703, COSV51831703; called by muse, mutect2, varscan2
- GNG12 | c.202del p.T68Lfs*22 | Frame Shift Del (DEL) | VAF 41/126 reads (33%) | catalogued as rs1022402829; called by mutect2, pindel, varscan2
- GNG5 | c.92C>T p.A31V | Missense Mutation (SNP) | VAF 67/156 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.424); catalogued as COSV99759885; called by muse, mutect2, varscan2
- GOLGA3 | c.1846G>A p.E616K | Missense Mutation (SNP) | VAF 26/49 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs769227923, COSV52635080; called by muse, mutect2, varscan2
- GOLGA5 | c.2056C>T p.R686C | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50832384; called by muse, mutect2, varscan2
- GPHN | c.575del p.P192Lfs*44 | Frame Shift Del (DEL) | VAF 14/82 reads (17%) | catalogued as COSV59472636; called by mutect2, pindel, varscan2
- GPN1 | c.994G>A p.E332K | Missense Mutation (SNP) | VAF 45/106 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.037); catalogued as COSV53113493; called by muse, mutect2, varscan2
- GPR137B | c.88C>T p.P30S | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.01); catalogued as COSV63990781; called by muse, mutect2, varscan2
- GPR149 | c.2051A>G p.D684G | Missense Mutation (SNP) | VAF 71/191 reads (37%) | SIFT tolerated (0.1); PolyPhen benign (0.056); catalogued as rs758420110, COSV67666395; called by muse, mutect2, varscan2
- GPR156 | c.1409A>C p.E470A | Missense Mutation (SNP) | VAF 32/76 reads (42%) | SIFT tolerated (0.43); PolyPhen benign (0.024); catalogued as COSV59938717; called by muse, mutect2, varscan2
- GPR52 | c.1034A>G p.Q345R | Missense Mutation (SNP) | VAF 33/81 reads (41%) | SIFT tolerated, low confidence (0.77); PolyPhen benign (0); catalogued as COSV52283905; called by muse, mutect2, varscan2
- GPR78 | c.218C>T p.P73L | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.986); catalogued as rs750628218, COSV66762696; called by muse, mutect2, varscan2
- GRAMD1A | c.832C>T p.P278S | Missense Mutation (SNP) | VAF 27/78 reads (35%) | SIFT tolerated (0.62); PolyPhen probably damaging (0.968); catalogued as rs781114140, COSV58766313; called by muse, mutect2, varscan2
- GRIA2 | c.295A>G p.T99A | Missense Mutation (SNP) | VAF 65/142 reads (46%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.838); catalogued as COSV52385677; called by muse, mutect2, varscan2
- GRIN2A | c.2816G>T p.G939V | Missense Mutation (SNP) | VAF 70/171 reads (41%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as COSV58025680; called by muse, mutect2, varscan2
- GRIN2D | c.1979T>C p.L660P | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as COSV54377655; called by muse, mutect2, varscan2
- GRIN3A | c.688C>T p.R230W | Missense Mutation (SNP) | VAF 24/49 reads (49%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.919); catalogued as rs1263242119, COSV62451922; called by muse, mutect2, varscan2
- GRM5 | c.3379G>A p.A1127T (on ENST00000305447 / NM_001143831.2; = p.A1095T on NM_000842.4) | Missense Mutation (SNP) | VAF 27/61 reads (44%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0); catalogued as rs747989546, COSV59596755; called by muse, mutect2, varscan2
- GRM6 | c.602C>T p.A201V | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as rs200306155, COSV51438936; called by mutect2, varscan2
- GSC | c.515T>G p.L172R | Missense Mutation (SNP) | VAF 32/76 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53076945; called by muse, mutect2, varscan2
- GSE1 | c.366del p.V123Wfs*2 | Frame Shift Del (DEL) | VAF 12/36 reads (33%) | catalogued as rs754199513; called by mutect2, varscan2
- GSTZ1 | c.511G>A p.A171T | Missense Mutation (SNP) | VAF 27/61 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.06); catalogued as rs866913315, COSV53623098; called by muse, mutect2, varscan2
- GSX2 | c.241G>T p.G81W | Missense Mutation (SNP) | VAF 18/30 reads (60%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.955); catalogued as rs752777000, COSV58842539; called by muse, mutect2, varscan2
- GSX2 | c.641T>C p.L214P | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100482609; called by muse, varscan2
- GTF2IRD2 | c.355T>C p.Y119H | Missense Mutation (SNP) | VAF 28/370 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs1422871321; called by muse, mutect2
- GUCY1A1 | c.544A>G p.R182G | Missense Mutation (SNP) | VAF 37/103 reads (36%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as rs1463137959, COSV56648943; called by muse, mutect2, varscan2
- GXYLT2 | c.600G>A p.P200= | Splice Region (SNP) | VAF 44/92 reads (48%) | catalogued as rs757737795, COSV67473737; called by muse, mutect2, varscan2
- GYPC | c.29C>T p.T10M | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.902); catalogued as COSV52145535; called by muse, mutect2, varscan2
- HCN3 | c.2122C>T p.R708W | Missense Mutation (SNP) | VAF 7/10 reads (70%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as rs763111047, COSV100713002; called by muse, mutect2, varscan2
- HCN4 | c.1178G>A p.R393H | Missense Mutation (SNP) | VAF 47/90 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs786205804, COSV56081300; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- HDAC4 | c.155G>A p.R52H | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs777568201, COSV61861923; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- HDAC7 | c.2476C>A p.Q826K (on ENST00000427332; = p.Q865K on NM_015401.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.407); catalogued as COSV50327506; called by muse, mutect2, varscan2
- HDLBP | c.1691A>G p.E564G | Missense Mutation (SNP) | VAF 104/270 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.363); catalogued as COSV60493196, COSV60501872; called by muse, varscan2
- HDLBP | c.1177C>T p.Q393* | Nonsense Mutation (SNP) | VAF 21/59 reads (36%) | catalogued as COSV60493210; called by muse, mutect2, varscan2
- HEATR5B | c.6214del p.*2072Nfs*3 | Frame Shift Del (DEL) | VAF 24/44 reads (55%) | catalogued as rs1315552549, COSV51848615; called by mutect2, varscan2
- HECW2 | c.2108C>T p.T703I | Missense Mutation (SNP) | VAF 19/36 reads (53%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.027); catalogued as COSV53653240; called by muse, mutect2, varscan2
- HELQ | c.1682del p.K561Rfs*8 | Frame Shift Del (DEL) | VAF 166/447 reads (37%) | catalogued as rs1560552678, COSV99787908; called by mutect2, pindel, varscan2
- HEMGN | c.1082C>A p.P361H | Missense Mutation (SNP) | VAF 146/323 reads (45%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.973); catalogued as COSV52325653; called by muse, mutect2, varscan2
- HERC1 | c.5341G>A p.V1781I | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT tolerated (0.66); PolyPhen benign (0.015); catalogued as rs779058478, COSV71246784; called by muse, mutect2, varscan2
- HERC3 | c.1911+2T>C p.X637_splice | Splice Site (SNP) | VAF 22/58 reads (38%) | catalogued as COSV52018613; called by muse, mutect2, varscan2
- HIC2 | c.481dup p.R161Pfs*40 | Frame Shift Ins (INS) | VAF 16/28 reads (57%) | catalogued as rs745918762; called by mutect2, varscan2
- HID1 | c.421del p.L141Wfs*62 | Frame Shift Del (DEL) | VAF 22/52 reads (42%) | catalogued as COSV59351209; called by mutect2, pindel, varscan2
- HIF3A | c.41T>G p.L14R (on ENST00000377670 / NM_152795.4; = p.L12R on NM_152794.4) | Missense Mutation (SNP) | VAF 54/120 reads (45%) | SIFT tolerated (1); PolyPhen possibly damaging (0.737); catalogued as COSV52196727; called by muse, mutect2, varscan2
- HIVEP2 | c.4845del p.S1616Afs*32 | Frame Shift Del (DEL) | VAF 37/92 reads (40%) | catalogued as COSV50038785; called by mutect2, pindel, varscan2
- HK1 | c.1763A>T p.Y588F | Missense Mutation (SNP) | VAF 43/99 reads (43%) | SIFT tolerated (0.33); PolyPhen benign (0.107); catalogued as COSV53855501; called by muse, mutect2, varscan2
- HLA-A | c.740A>G p.D247G | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100954647; called by muse, mutect2, varscan2
- HLA-G | c.391G>A p.G131R | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.997); catalogued as COSV100827183, COSV64405273; called by muse, mutect2, varscan2
- HMBS | c.904C>A p.P302T | Missense Mutation (SNP) | VAF 34/81 reads (42%) | SIFT tolerated (0.15); PolyPhen benign (0.345); catalogued as COSV53827943; called by muse, mutect2, varscan2
- HNRNPK | c.1240C>T p.R414C | Missense Mutation (SNP) | VAF 26/48 reads (54%) | SIFT deleterious (0.03); PolyPhen benign (0.017); catalogued as rs1348162749, COSV61088725; called by muse, mutect2, varscan2
- HNRNPL | c.1010del p.P337Hfs*58 | Frame Shift Del (DEL) | VAF 22/42 reads (52%) | catalogued as rs767148651; called by mutect2, varscan2
- HOOK3 | c.474G>A p.M158I | Missense Mutation (SNP) | VAF 69/129 reads (53%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as COSV100295879; called by muse, mutect2, varscan2
- HOXA9 | c.500A>G p.E167G | Missense Mutation (SNP) | VAF 40/88 reads (45%) | SIFT tolerated (0.24); PolyPhen benign (0.007); catalogued as rs369971422; called by muse, mutect2, varscan2
- HOXB7 | c.191del p.G64Afs*99 | Frame Shift Del (DEL) | VAF 16/30 reads (53%) | catalogued as rs761197780; called by mutect2, varscan2
- HPS4 | c.1015G>A p.A339T | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as rs758902895, COSV61102932; called by muse, mutect2, varscan2
- HPSE | c.992A>G p.E331G | Missense Mutation (SNP) | VAF 39/89 reads (44%) | SIFT tolerated (0.22); PolyPhen benign (0.022); catalogued as COSV60986024; called by muse, mutect2, varscan2
- HSPBAP1 | c.217C>T p.R73* | Nonsense Mutation (SNP) | VAF 89/195 reads (46%) | catalogued as rs763604278, COSV60241594; called by muse, mutect2, varscan2
- HSPG2 | c.8711C>T p.A2904V | Missense Mutation (SNP) | VAF 36/66 reads (55%) | SIFT tolerated (0.08); PolyPhen benign (0.101); catalogued as rs372570791; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- HTR1E | c.404C>T p.T135M | Missense Mutation (SNP) | VAF 41/96 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs143974435; called by muse, mutect2, varscan2
- HTR3C | c.919del p.L307Sfs*12 | Frame Shift Del (DEL) | VAF 19/57 reads (33%) | catalogued as rs1394232956; called by mutect2, pindel, varscan2
- HTR4 | c.916G>A p.G306R | Missense Mutation (SNP) | VAF 36/87 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.921); catalogued as rs763112819, COSV100086900, COSV58791437; called by muse, mutect2, varscan2
- HTRA3 | c.1276G>A p.V426M | Missense Mutation (SNP) | VAF 21/45 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); catalogued as rs1286807882, COSV56470216; called by muse, mutect2, varscan2
- HTT | c.1581G>T p.E527D | Missense Mutation (SNP) | VAF 41/119 reads (34%) | SIFT tolerated (0.37); PolyPhen benign (0.011); catalogued as COSV61859227; called by muse, mutect2, varscan2
- HYDIN | c.5684G>T p.G1895V | Missense Mutation (SNP) | VAF 51/130 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99993521; called by muse, mutect2, varscan2
- IAPP | c.124A>G p.T42A | Missense Mutation (SNP) | VAF 37/71 reads (52%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.492); catalogued as COSV53713281; called by muse, mutect2, varscan2
- IARS2 | c.2035G>A p.V679I | Missense Mutation (SNP) | VAF 52/126 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV56958452; called by muse, mutect2, varscan2
- IDH2 | c.560A>T p.D187V | Missense Mutation (SNP) | VAF 22/45 reads (49%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.117); catalogued as COSV57471388; called by muse, mutect2, varscan2
- IDO1 | c.1107A>C p.E369D | Missense Mutation (SNP) | VAF 30/70 reads (43%) | SIFT tolerated (0.36); PolyPhen benign (0.423); catalogued as COSV53713451; called by muse, mutect2, varscan2
- IFFO1 | c.1089del p.R364Gfs*47 (on ENST00000396840 / NM_001330324.2; = p.R367Gfs*47 on NM_080730.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 5/37 reads (14%) | catalogued as rs750779916, COSV60737300; called by mutect2, pindel, varscan2
- IFNA10 | c.5C>T p.A2V | Missense Mutation (SNP) | VAF 210/470 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.786); catalogued as COSV53330728; called by muse, mutect2, varscan2
- IFT172 | c.5050C>A p.L1684M | Missense Mutation (SNP) | VAF 32/91 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.164); catalogued as COSV51993594; called by muse, mutect2, varscan2
- IFT74 | c.1196A>G p.H399R | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT tolerated (0.1); PolyPhen benign (0.112); catalogued as COSV66286300; called by muse, mutect2, varscan2
- IGF1R | c.3472C>T p.R1158* | Nonsense Mutation (SNP) | VAF 30/64 reads (47%) | catalogued as rs1287599859, COSV51273582; called by muse, mutect2, varscan2
- IGF2R | c.2265C>A p.Y755* | Nonsense Mutation (SNP) | VAF 20/48 reads (42%) | catalogued as COSV63627386; called by muse, mutect2, varscan2
- IGHV1-24 | c.41C>T p.A14V | Missense Mutation (SNP) | VAF 44/86 reads (51%) | SIFT tolerated (0.2); PolyPhen benign (0.075); catalogued as rs551274235; called by muse, mutect2, varscan2
- IGHV1-58 | c.35G>A p.G12E | Missense Mutation (SNP) | VAF 27/61 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs782251124; called by muse, mutect2, varscan2
- IGHV2-70 | c.340T>C p.Y114H | Missense Mutation (SNP) | VAF 133/309 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs144976346; called by muse, mutect2, varscan2
- IGKV2-30 | c.301A>G p.S101G | Missense Mutation (SNP) | VAF 66/200 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.583); catalogued as rs776403623; called by muse, mutect2, varscan2
- IGSF10 | c.3014C>T p.P1005L | Missense Mutation (SNP) | VAF 33/148 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.588); catalogued as rs567335058, COSV56782916; called by muse, mutect2, varscan2
- IL12RB2 | c.1324C>T p.Q442* | Nonsense Mutation (SNP) | VAF 16/107 reads (15%) | catalogued as COSV52021388; called by muse, mutect2, varscan2
- IMPDH2 | c.188C>T p.T63I | Missense Mutation (SNP) | VAF 38/89 reads (43%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.98); catalogued as COSV58707532, COSV58707928; called by muse, mutect2, varscan2
- INA | c.944A>T p.Y315F | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.26); catalogued as COSV63975750; called by muse, mutect2, varscan2
- INSC | c.265G>A p.E89K | Missense Mutation (SNP) | VAF 27/58 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs201429164; called by muse, mutect2, varscan2
- INTS8 | c.1822C>T p.R608C | Missense Mutation (SNP) | VAF 64/134 reads (48%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.996); catalogued as COSV58249346; called by muse, mutect2, varscan2
- INTS9 | c.1141G>A p.G381R | Missense Mutation (SNP) | VAF 38/124 reads (31%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.971); catalogued as rs750163507, COSV68433547; called by muse, mutect2, varscan2
- IQCA1 | c.140T>C p.V47A | Missense Mutation (SNP) | VAF 43/117 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.211); catalogued as COSV54498512; called by muse, mutect2, varscan2
- IQCJ-SCHIP1 | c.903G>T p.E301D (on ENST00000485419 / NM_001197113.1; = p.E225D on NM_014575.3) | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.479); catalogued as COSV61841091; called by muse, mutect2, varscan2
- IRS1 | c.941C>G p.A314G | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV100524859; called by muse, mutect2, varscan2
- IRS4 | c.1772dup p.K592Qfs*12 | Frame Shift Ins (INS) | VAF 17/27 reads (63%) | catalogued as rs780982673; called by mutect2, varscan2
- ISLR | c.503C>T p.P168L | Missense Mutation (SNP) | VAF 12/19 reads (63%) | SIFT tolerated (0.05); PolyPhen benign (0.353); catalogued as rs371808969, COSV51433319, COSV99997602; called by muse, mutect2, varscan2
- ITGA4 | c.934G>T p.A312S | Missense Mutation (SNP) | VAF 189/477 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51998767; called by muse, mutect2, varscan2
- ITGA6 | c.373G>A p.G125R | Missense Mutation (SNP) | VAF 21/39 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV51220886; called by muse, mutect2, varscan2
- ITGB6 | c.1781G>A p.R594H | Missense Mutation (SNP) | VAF 40/103 reads (39%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); catalogued as rs757977525, COSV51791850; called by muse, mutect2, varscan2
- ITPR3 | c.3158G>A p.R1053H | Missense Mutation (SNP) | VAF 27/54 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs770956589, COSV65407100; called by muse, mutect2, varscan2
- ITPR3 | c.3430G>A p.A1144T | Missense Mutation (SNP) | VAF 31/76 reads (41%) | SIFT tolerated (0.49); PolyPhen benign (0.001); catalogued as rs971334984, COSV65407111; called by muse, mutect2, varscan2
- ITPR3 | c.4541T>C p.L1514P | Missense Mutation (SNP) | VAF 34/72 reads (47%) | SIFT tolerated (0.12); PolyPhen benign (0.015); catalogued as COSV65407116; called by muse, mutect2, varscan2
- JPH3 | c.1231A>G p.I411V | Missense Mutation (SNP) | VAF 46/92 reads (50%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as COSV99413873; called by muse, mutect2, varscan2
- JUP | c.1608G>T p.Q536H | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.522); catalogued as COSV60277482; called by muse, mutect2, varscan2
- KAT6A | c.5684G>A p.R1895H | Missense Mutation (SNP) | VAF 46/100 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.765); catalogued as COSV55904375; called by muse, mutect2, varscan2
- KATNB1 | c.440G>A p.S147N | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT tolerated (0.19); PolyPhen benign (0.091); catalogued as COSV65559819; called by muse, mutect2, varscan2
- KATNIP | c.3088G>A p.V1030M | Missense Mutation (SNP) | VAF 26/59 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs141253001; called by muse, varscan2
- KAZN | c.397A>G p.R133G | Missense Mutation (SNP) | VAF 29/71 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV63207249; called by muse, mutect2, varscan2
- KAZN | c.1496G>A p.R499H | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV65716287; called by muse, mutect2, varscan2
- KCNA4 | c.663del p.F221Lfs*21 | Frame Shift Del (DEL) | VAF 9/26 reads (35%) | catalogued as rs754892524; called by mutect2, pindel, varscan2
- KCNB2 | c.1747C>T p.Q583* | Nonsense Mutation (SNP) | VAF 38/70 reads (54%) | catalogued as COSV73049432; called by muse, mutect2, varscan2
- KCNC1 | c.351G>T p.E117D | Missense Mutation (SNP) | VAF 24/49 reads (49%) | SIFT tolerated (0.13); PolyPhen benign (0.156); catalogued as COSV56392665; called by muse, mutect2, varscan2
- KCNF1 | c.701C>T p.T234I | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54462411; called by muse, mutect2, varscan2
- KCNG4 | c.922G>A p.V308M | Missense Mutation (SNP) | VAF 29/61 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs139771972; called by muse, mutect2, varscan2
- KCNJ10 | c.305del p.P102Rfs*96 | Frame Shift Del (DEL) | VAF 14/34 reads (41%) | catalogued as rs765409185; called by mutect2, varscan2
- KCNJ5 | c.883C>T p.H295Y | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.028); catalogued as COSV57964240; called by muse, mutect2, varscan2
- KCNK7 | c.17C>T p.P6L | Missense Mutation (SNP) | VAF 48/109 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.185); catalogued as rs1475703483, COSV58418835; called by muse, mutect2, varscan2
- KCNMA1 | c.1723C>A p.L575I | Missense Mutation (SNP) | VAF 29/61 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); catalogued as COSV54236393; called by muse, mutect2, varscan2
- KCNQ2 | c.1273C>A p.L425M | Missense Mutation (SNP) | VAF 5/74 reads (7%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.897); catalogued as COSV100610476; called by muse, mutect2
- KCNQ2 | c.25G>A p.G9S | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.747); catalogued as COSV100610479; called by muse, mutect2, varscan2
- KCTD19 | c.2301dup p.V768Rfs*12 | Frame Shift Ins (INS) | VAF 26/91 reads (29%) | catalogued as rs759860142; called by mutect2, varscan2
- KIAA0319 | c.1280-1G>A p.X427_splice | Splice Site (SNP) | VAF 14/34 reads (41%) | catalogued as COSV65497166; called by muse, varscan2
- KIAA0513 | c.212G>A p.R71H | Missense Mutation (SNP) | VAF 17/34 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as rs1177796146, COSV50740824; called by muse, mutect2, varscan2
- KIAA1109 | c.6124G>A p.V2042I | Missense Mutation (SNP) | VAF 46/94 reads (49%) | SIFT tolerated (0.61); PolyPhen benign (0.055); catalogued as COSV52666183; called by muse, mutect2, varscan2
- KIAA1522 | c.985G>A p.A329T (on ENST00000373480 / NM_001198972.2; = p.A388T on NM_020888.3) | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1160448393, COSV99615010; called by muse, mutect2, varscan2
- KIAA1549L | c.5267C>T p.S1756L (on ENST00000321505; = p.S2053L on NM_012194.3) | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1205996425, COSV58584314; called by muse, mutect2, varscan2
- KIF26A | c.3282del p.L1096Wfs*152 | Frame Shift Del (DEL) | VAF 7/17 reads (41%) | catalogued as rs745639630; called by mutect2, varscan2
- KIF5A | c.3096C>A p.S1032R | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.969); catalogued as COSV54052738; called by muse, mutect2
- KIF5B | c.2886A>T p.Q962H | Missense Mutation (SNP) | VAF 45/96 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.948); catalogued as COSV56651690; called by muse, mutect2, varscan2
- KIF6 | c.611del p.L204* | Frame Shift Del (DEL) | VAF 49/126 reads (39%) | catalogued as rs777890702; called by mutect2, varscan2
- KIF6 | c.107T>C p.L36S | Missense Mutation (SNP) | VAF 45/99 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV54671396; called by muse, mutect2, varscan2
- KIF7 | c.2585G>A p.R862H | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.697); catalogued as rs202057334; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KLC1 | c.1528C>T p.L510F | Missense Mutation (SNP) | VAF 28/52 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV55806776; called by muse, mutect2, varscan2
- KLHL31 | c.312del p.D105Tfs*15 | Frame Shift Del (DEL) | VAF 48/120 reads (40%) | catalogued as rs1227078726; called by mutect2, varscan2
- KLHL40 | c.494G>A p.R165H | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.703); catalogued as COSV99825723; called by muse, mutect2
- KLHL42 | c.1194del p.C399Vfs*44 | Frame Shift Del (DEL) | VAF 12/36 reads (33%) | catalogued as rs749194179; called by mutect2, pindel, varscan2
- KLK4 | c.448G>A p.V150I | Missense Mutation (SNP) | VAF 24/41 reads (59%) | SIFT tolerated (0.28); PolyPhen benign (0.011); catalogued as rs970897746, COSV60675970; called by muse, mutect2, varscan2
- KMT2A | c.11708G>A p.R3903H | Missense Mutation (SNP) | VAF 31/99 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63282338; called by muse, mutect2, varscan2
- KMT2B | c.1976T>C p.L659P | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.056); catalogued as rs1311247867, COSV99386220; called by muse, mutect2, varscan2
- KNL1 | c.1244A>G p.H415R (on ENST00000346991 / NM_170589.5; = p.H389R on NM_144508.5) | Missense Mutation (SNP) | VAF 49/102 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV61152749; called by muse, mutect2, varscan2
- KRT10 | c.361G>A p.G121S | Missense Mutation (SNP) | VAF 46/114 reads (40%) | SIFT tolerated (0.37); PolyPhen benign (0.013); catalogued as rs568226045, COSV54089009; called by muse, varscan2
- KRT16 | c.851G>A p.R284H | Missense Mutation (SNP) | VAF 45/88 reads (51%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.954); catalogued as rs146562738; called by muse, mutect2, varscan2
- LAMA2 | c.2530T>G p.C844G | Missense Mutation (SNP) | VAF 53/136 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV70342662; called by muse, mutect2, varscan2
- LAMA2 | c.3372del p.K1124Nfs*15 | Frame Shift Del (DEL) | VAF 30/95 reads (32%) | catalogued as rs1361925574, COSV70347760; called by mutect2, pindel, varscan2
- LAMA2 | c.6201_6203del p.K2067del | In Frame Del (DEL) | VAF 48/124 reads (39%) | catalogued as rs758495000; called by pindel, varscan2
- LAMB1 | c.3344G>A p.S1115N | Missense Mutation (SNP) | VAF 28/67 reads (42%) | SIFT tolerated (0.12); PolyPhen benign (0.031); catalogued as COSV55962906; called by muse, mutect2, varscan2
- LAMB2 | c.82G>A p.A28T | Missense Mutation (SNP) | VAF 21/44 reads (48%) | SIFT tolerated (0.19); PolyPhen benign (0.073); catalogued as rs1259349624, COSV59731860; called by muse, mutect2, varscan2
- LARP6 | c.1174G>A p.V392I | Missense Mutation (SNP) | VAF 28/67 reads (42%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs561519879, COSV54579381; called by muse, mutect2, varscan2
- LATS1 | c.2416C>T p.R806* | Nonsense Mutation (SNP) | VAF 45/121 reads (37%) | catalogued as COSV53588033; called by muse, mutect2, varscan2
- LBX1 | c.574G>T p.E192* | Nonsense Mutation (SNP) | VAF 13/36 reads (36%) | catalogued as COSV64621573; called by muse, mutect2, varscan2
- LDAH | c.107A>G p.H36R | Missense Mutation (SNP) | VAF 15/126 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs761059091, COSV99425855; called by mutect2, varscan2
- LDB2 | c.1072G>A p.A358T | Missense Mutation (SNP) | VAF 197/451 reads (44%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs768789036, COSV58765087; called by muse, mutect2, varscan2
- LEFTY2 | c.498-2A>G p.X166_splice | Splice Site (SNP) | VAF 18/41 reads (44%) | catalogued as rs761287888, COSV64746569; called by muse, mutect2, varscan2
- LGI1 | c.254G>A p.G85E | Missense Mutation (SNP) | VAF 37/71 reads (52%) | SIFT tolerated (0.11); PolyPhen benign (0.219); catalogued as COSV65057671; called by muse, mutect2, varscan2
- LGR5 | c.539A>C p.Q180P | Missense Mutation (SNP) | VAF 54/135 reads (40%) | SIFT tolerated (0.13); PolyPhen benign (0.433); catalogued as COSV57002615, COSV57003600; called by muse, mutect2, varscan2
- LILRB5 | c.760G>A p.V254I | Missense Mutation (SNP) | VAF 29/90 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.02); catalogued as rs145477663, COSV100300716; called by muse, mutect2, varscan2
- LIPT1 | c.46A>G p.N16D | Missense Mutation (SNP) | VAF 144/346 reads (42%) | SIFT tolerated (0.34); PolyPhen benign (0.015); catalogued as COSV60739430; called by muse, mutect2, varscan2
- LMF2 | c.1628A>G p.Q543R | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.158); catalogued as COSV53316675; called by muse, mutect2, varscan2
- LMF2 | c.1052-2A>G p.X351_splice | Splice Site (SNP) | VAF 21/69 reads (30%) | catalogued as rs1569518380, COSV53316686; called by muse, mutect2, varscan2
- LMX1A | c.580C>T p.R194C | Missense Mutation (SNP) | VAF 84/171 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs149908681, COSV54227573; called by muse, mutect2, varscan2
- LPAR5 | c.145C>T p.R49C | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.506); catalogued as rs769378579, COSV61692216; called by muse, mutect2, varscan2
- LPCAT1 | c.578G>A p.R193Q | Missense Mutation (SNP) | VAF 34/75 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs780038428, COSV52036357; called by muse, mutect2, varscan2
- LPIN1 | c.1190T>C p.V397A | Missense Mutation (SNP) | VAF 50/128 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.354); catalogued as COSV56763402; called by muse, mutect2, varscan2
- LPIN3 | c.1409del p.N470Tfs*10 | Frame Shift Del (DEL) | VAF 30/86 reads (35%) | catalogued as rs1412227875; called by mutect2, pindel, varscan2
- LRFN2 | c.332G>A p.R111Q | Missense Mutation (SNP) | VAF 20/38 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs1188072304, COSV57825218; called by muse, mutect2, varscan2
- LRP1 | c.10405del p.R3469Gfs*24 | Frame Shift Del (DEL) | VAF 22/54 reads (41%) | catalogued as COSV54520204; called by mutect2, pindel, varscan2
- LRP1 | c.13258C>T p.H4420Y | Missense Mutation (SNP) | VAF 25/55 reads (45%) | SIFT tolerated (0.93); PolyPhen benign (0.019); catalogued as rs374622388; called by muse, mutect2, varscan2
- LRP4 | c.1496G>A p.G499D | Missense Mutation (SNP) | VAF 31/81 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV66134785; called by muse, mutect2, varscan2
- LRP6 | c.454A>G p.M152V | Missense Mutation (SNP) | VAF 35/67 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.304); catalogued as COSV53784814, COSV53788966; called by muse, mutect2, varscan2
- LRRC15 | c.1330A>G p.R444G | Missense Mutation (SNP) | VAF 29/61 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.011); catalogued as COSV61649763; called by muse, mutect2, varscan2
- LRRC23 | c.536T>C p.I179T | Missense Mutation (SNP) | VAF 24/50 reads (48%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as COSV50387406; called by muse, mutect2, varscan2
- LRRC27 | c.1171-1G>T p.X391_splice | Splice Site (SNP) | VAF 24/64 reads (38%) | catalogued as COSV63996462; called by muse, mutect2, varscan2
- LRRC29 | c.667C>T p.L223F | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV58526806; called by muse, mutect2, varscan2
- LRRC30 | c.71G>T p.R24I | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT tolerated (0.1); PolyPhen benign (0.347); catalogued as COSV67301491, COSV67301981; called by muse, mutect2, varscan2
- LRRC36 | c.701A>G p.Q234R | Missense Mutation (SNP) | VAF 43/113 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs771054996, COSV52078734; called by muse, mutect2, varscan2
- LRRC37A | c.3912del p.K1304Nfs*11 | Frame Shift Del (DEL) | VAF 12/72 reads (17%) | catalogued as rs1353691875, COSV57225514; called by mutect2, varscan2
- LRRC66 | c.1078C>T p.R360C | Missense Mutation (SNP) | VAF 37/121 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.683); catalogued as COSV100603099, COSV58632676; called by muse, mutect2, varscan2
- LRRC8A | c.65C>T p.P22L | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs757315550, COSV52184775; called by muse, mutect2, varscan2
- LRRC8A | c.2036C>T p.T679I | Missense Mutation (SNP) | VAF 27/52 reads (52%) | SIFT tolerated (0.18); PolyPhen benign (0.079); catalogued as rs748626839, COSV52184789; called by muse, mutect2, varscan2
- LRRCC1 | c.235A>G p.R79G | Missense Mutation (SNP) | VAF 83/179 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.03); catalogued as rs780720174, COSV64482978; called by muse, mutect2, varscan2
- LRRK2 | c.955C>A p.L319I | Missense Mutation (SNP) | VAF 30/63 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV54147720; called by muse, mutect2, varscan2
- LRRN4 | c.1123C>A p.P375T | Missense Mutation (SNP) | VAF 70/142 reads (49%) | SIFT tolerated (0.23); PolyPhen benign (0.009); catalogued as COSV66644828; called by muse, mutect2, varscan2
- LRRN4CL | c.274C>T p.R92C | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.765); catalogued as COSV54015010; called by muse, mutect2, varscan2
- LSM10 | c.101G>A p.R34Q | Missense Mutation (SNP) | VAF 31/58 reads (53%) | SIFT tolerated (0.06); PolyPhen benign (0.341); catalogued as rs139161560; called by muse, mutect2, varscan2
- LYG2 | c.227C>T p.A76V | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT tolerated (0.46); PolyPhen benign (0.003); catalogued as COSV60715453; called by muse, mutect2, varscan2
- MAB21L1 | c.646C>A p.H216N | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV100083304; called by muse, mutect2, varscan2
- MAB21L4 | c.65T>C p.L22P | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as COSV100278674; called by muse, mutect2
- MAGEC1 | c.366G>T p.E122D | Missense Mutation (SNP) | VAF 72/82 reads (88%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.217); catalogued as COSV99596327; called by muse, mutect2, varscan2
- MAGEE1 | c.1006G>A p.A336T | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as rs1556839531, COSV63909288; called by muse, mutect2, varscan2
- MAGEE1 | c.1802C>T p.A601V | Missense Mutation (SNP) | VAF 31/36 reads (86%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); catalogued as COSV63909294; called by muse, mutect2, varscan2
- MAML1 | c.1271C>G p.P424R | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); catalogued as COSV52983354, COSV52989105, COSV99483322; called by mutect2, varscan2
- MAML1 | c.1349C>T p.A450V | Missense Mutation (SNP) | VAF 27/80 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.114); catalogued as COSV52983858; called by muse, mutect2, varscan2
- MAN2A1 | c.1404del p.F468Lfs*22 | Frame Shift Del (DEL) | VAF 31/87 reads (36%) | catalogued as rs766462976; called by mutect2, pindel, varscan2
- MAN2A1 | c.1709A>T p.D570V | Missense Mutation (SNP) | VAF 229/498 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54847723; called by muse, mutect2, varscan2
- MAN2B1 | c.1022C>T p.A341V | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.169); catalogued as rs574049175, COSV55470075; called by muse, mutect2, varscan2
- MAP2K2 | c.743C>T p.S248L | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs761669626, COSV53563505; called by muse, mutect2, varscan2
- MAP7 | c.563C>T p.S188L | Missense Mutation (SNP) | VAF 56/124 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs371940141; called by muse, varscan2
- MAPK8 | c.1021C>T p.Q341* | Nonsense Mutation (SNP) | VAF 39/84 reads (46%) | catalogued as COSV64408631; called by muse, mutect2, varscan2
- MAPK8IP3 | c.301C>T p.R101C | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV50188620; called by muse, mutect2, varscan2
- MAPRE3 | c.668G>A p.R223H | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs766068888, COSV51866595; called by muse, mutect2, varscan2
- MARCHF2 | c.207G>T p.E69D | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.85); catalogued as COSV53104525; called by muse, mutect2, varscan2
- MAST1 | c.4330G>A p.G1444R | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.003); catalogued as rs377752846, COSV52243205; called by muse, mutect2, varscan2
- MASTL | c.683del p.N228Ifs*28 | Frame Shift Del (DEL) | VAF 31/65 reads (48%) | catalogued as rs1273510260; called by mutect2, varscan2
- MBD5 | c.1427C>T p.P476L | Missense Mutation (SNP) | VAF 29/61 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.173); catalogued as COSV68696232; called by muse, mutect2, varscan2
- MBTD1 | c.1097C>T p.T366I | Missense Mutation (SNP) | VAF 55/125 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.218); catalogued as COSV64503040; called by muse, mutect2, varscan2
- MCOLN2 | c.406A>G p.N136D | Missense Mutation (SNP) | VAF 35/86 reads (41%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52294171; called by muse, mutect2, varscan2
- MDN1 | c.8164C>T p.R2722W | Missense Mutation (SNP) | VAF 28/56 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs372082293; called by muse, mutect2, varscan2
- MDN1 | c.5966del p.K1989Rfs*65 | Frame Shift Del (DEL) | VAF 20/56 reads (36%) | catalogued as rs750092100; called by mutect2, varscan2
- MEAK7 | c.891G>T p.E297D | Missense Mutation (SNP) | VAF 29/71 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.881); catalogued as COSV59143589; called by muse, mutect2
- MED12 | c.3406A>G p.I1136V | Missense Mutation (SNP) | VAF 33/39 reads (85%) | SIFT tolerated (0.3); PolyPhen benign (0.13); catalogued as COSV61335082, COSV61357151; called by muse, mutect2, varscan2
- MEFV | c.1060del p.R354Gfs*14 | Frame Shift Del (DEL) | VAF 41/108 reads (38%) | catalogued as CM035568, COSV54824683; called by mutect2, pindel, varscan2
- MEGF6 | c.560G>A p.C187Y | Missense Mutation (SNP) | VAF 39/83 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53887714; called by muse, mutect2, varscan2
- MEGF8 | c.4102G>A p.G1368S (on ENST00000251268 / NM_001271938.2; = p.G1301S on NM_001410.3) | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as rs758888823, COSV52078630; called by muse, mutect2, varscan2
- MEIG1 | c.161G>A p.G54E | Missense Mutation (SNP) | VAF 57/153 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65542471; called by muse, mutect2, varscan2
- MERTK | c.1408G>A p.G470R | Missense Mutation (SNP) | VAF 52/104 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54926095; called by muse, mutect2, varscan2
- METTL3 | c.1706A>G p.Y569C | Missense Mutation (SNP) | VAF 35/87 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as COSV52968022; called by muse, mutect2, varscan2
- METTL5 | c.280G>A p.A94T | Missense Mutation (SNP) | VAF 64/136 reads (47%) | SIFT tolerated (0.27); PolyPhen benign (0.05); catalogued as COSV53626155; called by muse, mutect2, varscan2
- MFSD1 | c.752-1G>A p.X251_splice | Splice Site (SNP) | VAF 84/190 reads (44%) | catalogued as COSV51839760; called by muse, mutect2, varscan2
- MGAT5B | c.1600G>A p.G534S (on ENST00000569840 / NM_001199172.2; = p.G532S on NM_144677.3) | Missense Mutation (SNP) | VAF 19/36 reads (53%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); catalogued as COSV56927055, COSV56930271; called by muse, mutect2, varscan2
- MIDEAS | c.992C>A p.P331Q | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as COSV54093534, COSV54096712; called by muse, mutect2, varscan2
- MINAR1 | c.1485G>T p.Q495H | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT tolerated, low confidence (0.43); PolyPhen possibly damaging (0.459); catalogued as COSV59581619; called by muse, mutect2, varscan2
- MIS18BP1 | c.1139del p.N380Ifs*3 | Frame Shift Del (DEL) | VAF 50/108 reads (46%) | catalogued as rs751180035; called by mutect2, varscan2
- MIXL1 | c.353G>A p.R118H | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT tolerated (0.06); PolyPhen benign (0.417); catalogued as COSV64729070; called by muse, mutect2, varscan2
- MKRN3 | c.862G>A p.A288T | Missense Mutation (SNP) | VAF 49/95 reads (52%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.789); catalogued as rs1469191304, COSV100091520, COSV58812333; called by muse, mutect2, varscan2
- MMP3 | c.491C>T p.A164V | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT tolerated (0.44); PolyPhen benign (0.011); catalogued as COSV100242992; called by muse, varscan2
- MMUT | c.133G>A p.A45T | Missense Mutation (SNP) | VAF 66/141 reads (47%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); catalogued as COSV51272733; called by muse, mutect2, varscan2
- MN1 | c.3724G>A p.D1242N | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.998); catalogued as rs1156484834, COSV56557078; called by muse, mutect2, varscan2
- MOAP1 | c.284C>T p.P95L | Missense Mutation (SNP) | VAF 35/53 reads (66%) | SIFT deleterious (0.01); PolyPhen benign (0.299); catalogued as COSV52092315; called by muse, mutect2, varscan2
- MOCOS | c.2527A>G p.M843V | Missense Mutation (SNP) | VAF 63/145 reads (43%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs747252798, COSV54340552; called by muse, mutect2, varscan2
- MON1A | c.695C>A p.P232H | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.391); catalogued as COSV56559874; called by muse, mutect2, varscan2
- MON2 | c.508C>T p.R170* | Nonsense Mutation (SNP) | VAF 52/126 reads (41%) | catalogued as rs1424459395, COSV54804809; called by muse, mutect2, varscan2
- MON2 | c.4094T>C p.L1365S | Missense Mutation (SNP) | VAF 55/142 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.199); catalogued as COSV54804827; called by muse, mutect2, varscan2
- MON2 | c.4223C>T p.P1408L | Missense Mutation (SNP) | VAF 145/356 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.415); catalogued as rs994875011, COSV54803784; called by muse, mutect2, varscan2
- MPHOSPH9 | c.1194+2T>C p.X398_splice | Splice Site (SNP) | VAF 15/30 reads (50%) | catalogued as COSV56617925; called by muse, mutect2, varscan2
- MRGPRX2 | c.947G>T p.C316F | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV61673966; called by muse, mutect2, varscan2
- MROH7 | c.1582A>G p.K528E | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT tolerated (0.19); PolyPhen benign (0.006); catalogued as COSV59869474; called by muse, mutect2, varscan2
- MRPL1 | c.265A>C p.K89Q | Missense Mutation (SNP) | VAF 20/142 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.328); catalogued as COSV100214008; called by muse, mutect2, varscan2
- MRPL48 | c.164G>A p.G55D | Missense Mutation (SNP) | VAF 21/41 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as rs780130166, COSV60210776; called by muse, mutect2, varscan2
- MRPL55 | c.352C>T p.R118C | Missense Mutation (SNP) | VAF 20/35 reads (57%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.817); catalogued as rs758299560, COSV54342128; called by muse, mutect2, varscan2
- MRPS11 | c.490G>A p.G164R | Missense Mutation (SNP) | VAF 25/47 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs372417211; called by muse, mutect2, varscan2
- MRPS27 | c.695-2A>G p.X232_splice | Splice Site (SNP) | VAF 22/52 reads (42%) | catalogued as COSV54649316; called by muse, mutect2, varscan2
- MRTFA | c.2123A>G p.H708R | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.564); catalogued as COSV100844320; called by muse, mutect2, varscan2
- MSH2 | c.2215G>A p.A739T | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51876943; called by muse, mutect2, varscan2
- MSH3 | c.746G>A p.C249Y | Missense Mutation (SNP) | VAF 106/215 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.645); catalogued as COSV54147212; called by muse, mutect2, varscan2
- MSLNL | c.961C>T p.H321Y | Missense Mutation (SNP) | VAF 39/64 reads (61%) | SIFT tolerated (0.73); PolyPhen benign (0.212); catalogued as COSV99558612; called by muse, mutect2, varscan2
- MTCL1 | c.1811del p.G604Afs*38 (on ENST00000306329 / NM_001378206.1; = p.G244Afs*38 on NM_015210.4) | Frame Shift Del (DEL) | VAF 13/33 reads (39%) | catalogued as COSV60406815; called by mutect2, pindel, varscan2
- MTF2 | c.788C>A p.P263Q | Missense Mutation (SNP) | VAF 58/142 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV64769949; called by muse, varscan2
- MTUS2 | c.667C>A p.H223N | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.099); catalogued as rs930596334, COSV70914992; called by muse, mutect2, varscan2
- MTUS2 | c.1477C>T p.R493C | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs779266664, COSV70914997; called by muse, mutect2, varscan2
- MUC16 | c.32528del p.F10843Sfs*11 | Frame Shift Del (DEL) | VAF 40/104 reads (38%) | catalogued as COSV67467225; called by pindel, varscan2
- MUL1 | c.758C>T p.A253V | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.005); catalogued as COSV51641003; called by muse, mutect2, varscan2
- MUS81 | c.1414C>T p.R472* | Nonsense Mutation (SNP) | VAF 10/29 reads (34%) | catalogued as rs771900946, COSV57259526; called by muse, mutect2, varscan2
- MX2 | c.1921C>T p.L641F | Missense Mutation (SNP) | VAF 31/54 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV58095741; called by muse, mutect2, varscan2
- MXD3 | c.148dup p.Q50Pfs*15 | Frame Shift Ins (INS) | VAF 16/44 reads (36%) | catalogued as rs866699857; called by mutect2, varscan2
- MXRA8 | c.901del p.R301Gfs*107 | Frame Shift Del (DEL) | VAF 16/34 reads (47%) | catalogued as rs764857791; called by mutect2, pindel
- MYBPC2 | c.214G>A p.V72M | Missense Mutation (SNP) | VAF 32/64 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.029); catalogued as rs147768888, COSV63094060; called by muse, mutect2, varscan2
- MYBPH | c.1286G>A p.R429H | Missense Mutation (SNP) | VAF 48/103 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as rs750570762, COSV55141180; called by muse, mutect2, varscan2
- MYBPH | c.1207T>C p.C403R | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.945); catalogued as rs369592636, COSV55141809; called by muse, mutect2, varscan2
- MYEOV | c.487G>A p.A163T | Missense Mutation (SNP) | VAF 64/136 reads (47%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.06); catalogued as COSV58293709; called by muse, mutect2, varscan2
- MYH1 | c.653C>T p.T218I | Missense Mutation (SNP) | VAF 34/75 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.956); catalogued as COSV56845423; called by muse, mutect2, varscan2
- MYH10 | c.1744G>A p.G582R | Missense Mutation (SNP) | VAF 35/83 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52597131; called by muse, mutect2, varscan2
- MYH13 | c.5378C>T p.T1793M | Missense Mutation (SNP) | VAF 64/142 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.305); catalogued as rs773006118, COSV52823185; called by muse, mutect2, varscan2
- MYH14 | c.5933C>A p.P1978H | Missense Mutation (SNP) | VAF 29/50 reads (58%) | SIFT deleterious (0.04); PolyPhen benign (0.439); catalogued as COSV51813019; called by muse, mutect2, varscan2
- MYH6 | c.5456C>T p.A1819V | Missense Mutation (SNP) | VAF 28/59 reads (47%) | SIFT tolerated (0.06); PolyPhen benign (0.056); catalogued as rs1375850340, COSV59305204; called by muse, mutect2, varscan2
- MYH7 | c.1163T>C p.M388T | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.624); catalogued as CM066921, COSV100806494; called by muse, mutect2, varscan2
- MYO15A | c.4087G>A p.V1363I | Missense Mutation (SNP) | VAF 36/83 reads (43%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.898); catalogued as rs374602753; called by muse, mutect2, varscan2
- MYO1D | c.1813C>T p.R605C | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs375202047; called by muse, mutect2, varscan2
- MYO1F | c.151G>A p.G51S | Missense Mutation (SNP) | VAF 48/94 reads (51%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs371689599; called by muse, mutect2, varscan2
- MYO3A | c.3539A>C p.E1180A | Missense Mutation (SNP) | VAF 35/95 reads (37%) | SIFT deleterious (0.05); PolyPhen benign (0.024); catalogued as rs904223720, COSV56323861, COSV99779646; called by muse, mutect2, varscan2
- MYO7A | c.1623del p.K542Rfs*80 | Frame Shift Del (DEL) | VAF 12/86 reads (14%) | catalogued as COSV68685202; called by mutect2, pindel, varscan2
- MYO7A | c.6116C>T p.A2039V | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs867558819, COSV68684035; called by muse, mutect2, varscan2
- MYSM1 | c.665_667del p.E222del | In Frame Del (DEL) | VAF 74/169 reads (44%) | catalogued as rs762364885; called by pindel, varscan2
- N4BP2L1 | c.511C>T p.R171* | Nonsense Mutation (SNP) | VAF 109/248 reads (44%) | catalogued as rs1244495987, COSV58412418; called by muse, mutect2, varscan2
- NAB1 | c.281T>C p.I94T | Missense Mutation (SNP) | VAF 28/64 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.061); catalogued as COSV61608421; called by muse, mutect2, varscan2
- NAGS | c.18G>T p.M6I | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); catalogued as COSV53227113; called by muse, mutect2, varscan2
- NAT2 | c.160G>A p.A54T | Missense Mutation (SNP) | VAF 23/129 reads (18%) | SIFT tolerated (0.46); PolyPhen benign (0.015); catalogued as COSV54061533; called by muse, mutect2, varscan2
- NBPF1 | c.2613C>T p.G871= | Splice Region (SNP) | VAF 28/41 reads (68%) | catalogued as rs374641830; called by muse, mutect2, varscan2
- NCAPD3 | c.1715G>A p.C572Y | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.137); catalogued as rs1018933941, COSV73258031; called by muse, mutect2, varscan2
- NCF4 | c.868G>A p.A290T | Missense Mutation (SNP) | VAF 45/96 reads (47%) | SIFT tolerated (0.41); PolyPhen benign (0.005); catalogued as rs753588526, COSV50620743; called by muse, mutect2, varscan2
- NCKIPSD | c.1583C>T p.T528M | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.255); catalogued as rs775376697, COSV99584183; called by muse, mutect2, varscan2
- NCL | c.78_80del p.E26del | In Frame Del (DEL) | VAF 40/108 reads (37%) | catalogued as rs752943861; called by pindel, varscan2
- NCOR2 | c.4826C>T p.S1609L | Missense Mutation (SNP) | VAF 38/79 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs767880178, COSV62295501; called by muse, mutect2, varscan2
- NCOR2 | c.2045A>G p.K682R | Missense Mutation (SNP) | VAF 27/60 reads (45%) | SIFT tolerated (0.23); PolyPhen benign (0.319); catalogued as COSV62295511; called by muse, mutect2, varscan2
- NDN | c.551G>A p.R184H | Missense Mutation (SNP) | VAF 29/67 reads (43%) | SIFT tolerated (0.2); PolyPhen benign (0.015); catalogued as rs765248776, COSV59358232; called by muse, mutect2, varscan2
- NDST2 | c.566T>C p.L189P | Missense Mutation (SNP) | VAF 24/38 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55212973, COSV55213427; called by muse, mutect2, varscan2
- NDUFA4 | c.135G>A p.W45* | Nonsense Mutation (SNP) | VAF 21/37 reads (57%) | catalogued as CM109845, COSV60011829; called by muse, mutect2, varscan2
- NEB | c.17035G>T p.E5679* | Nonsense Mutation (SNP) | VAF 41/117 reads (35%) | catalogued as COSV50874853; called by muse, mutect2, varscan2
- NEB | c.157G>A p.A53T | Missense Mutation (SNP) | VAF 83/174 reads (48%) | SIFT tolerated, low confidence (0.31); PolyPhen probably damaging (0.986); catalogued as COSV50875088; called by muse, mutect2, varscan2
- NECTIN3 | c.116T>C p.L39P | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.973); catalogued as COSV100162658; called by muse, mutect2, varscan2
- NEO1 | c.1229G>A p.C410Y | Missense Mutation (SNP) | VAF 44/92 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99982635; called by muse, mutect2, varscan2
- NEURL1 | c.1285C>T p.P429S | Missense Mutation (SNP) | VAF 14/24 reads (58%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.996); catalogued as COSV63914014; called by muse, mutect2, varscan2
- NFIL3 | c.1329G>T p.E443D | Missense Mutation (SNP) | VAF 66/132 reads (50%) | SIFT tolerated (0.05); PolyPhen benign (0.067); catalogued as COSV52683321; called by muse, mutect2, varscan2
- NFYA | c.722C>A p.P241H | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV58198108; called by muse, mutect2, varscan2
- NIN | c.3698del p.K1233Rfs*3 | Frame Shift Del (DEL) | VAF 22/52 reads (42%) | catalogued as rs34636266; called by mutect2, varscan2
- NINL | c.2142C>A p.C714* | Nonsense Mutation (SNP) | VAF 10/28 reads (36%) | catalogued as COSV54000083; called by muse, mutect2, varscan2
- NLN | c.1766A>G p.H589R | Missense Mutation (SNP) | VAF 30/76 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66765229; called by muse, mutect2, varscan2
- NLRP1 | c.2818C>T p.R940* | Nonsense Mutation (SNP) | VAF 11/31 reads (35%) | catalogued as rs193920788, COSV52557794, COSV52567498; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NLRP3 | c.2741A>G p.H914R | Missense Mutation (SNP) | VAF 45/111 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV60221656; called by muse, mutect2, varscan2
- NLRX1 | c.2489A>G p.Q830R | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT tolerated (0.98); PolyPhen benign (0); catalogued as COSV52702639; called by muse, mutect2, varscan2
- NMUR2 | c.352G>T p.G118C | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54917894, COSV54922819; called by muse, mutect2, varscan2
- NOD1 | c.1477A>G p.M493V | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV99768430; called by muse, mutect2, varscan2
- NOL11 | c.941A>G p.Y314C | Missense Mutation (SNP) | VAF 36/127 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as rs1245848160, COSV53522621; called by muse, mutect2, varscan2
- NOL4L | c.396del p.Y133Tfs*20 | Frame Shift Del (DEL) | VAF 10/30 reads (33%) | catalogued as rs751187638; called by mutect2, varscan2
- NOL8 | c.1169del p.N390Mfs*45 | Frame Shift Del (DEL) | VAF 40/87 reads (46%) | catalogued as rs757782481; called by mutect2, varscan2
- NONO | c.562T>C p.S188P | Missense Mutation (SNP) | VAF 27/31 reads (87%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as COSV52136417; called by muse, mutect2, varscan2
- NOP14 | c.2285C>A p.P762Q | Missense Mutation (SNP) | VAF 43/78 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs762920436, COSV58624527; called by muse, mutect2, varscan2
- NOP58 | c.563G>A p.G188D | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as COSV51896019; called by muse, mutect2, varscan2
- NOS3 | c.1319del p.G440Afs*64 | Frame Shift Del (DEL) | VAF 18/49 reads (37%) | catalogued as rs749517498, COSV52496454; called by mutect2, pindel, varscan2
- NPAS2 | c.2471G>A p.R824Q | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); catalogued as rs1274794081, COSV59556328; called by muse, varscan2
- NPAT | c.2162A>G p.D721G | Missense Mutation (SNP) | VAF 33/84 reads (39%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as COSV53716969; called by muse, mutect2, varscan2
- NPFFR1 | c.636G>A p.M212I | Missense Mutation (SNP) | VAF 30/68 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV53332519; called by muse, varscan2
- NPHP3 | c.2120C>T p.A707V | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT deleterious (0.05); PolyPhen benign (0.022); catalogued as COSV58628891; called by muse, mutect2, varscan2
- NPNT | c.1346-2A>G p.X449_splice | Splice Site (SNP) | VAF 32/56 reads (57%) | catalogued as COSV59752551; called by muse, varscan2
- NPSR1 | c.623C>T p.T208I | Missense Mutation (SNP) | VAF 44/89 reads (49%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as COSV62198417; called by muse, mutect2, varscan2
1,332 further variants in this file (826 protein-altering or splice-affecting, 459 silent, 47 other) are not listed here.
